Somatic mutation profile of tumor specimen 21cab01c-e968-42cc-9651-1e53c0 (aliquot 21cab01c-e968-42cc-9651-1e53c0_D6_1) from CPTAC case 11CO036, project CPTAC-2 (Colon — Adenomas and Adenocarcinomas). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Colon, NOS; AJCC pathologic stage: Stage IIIB.
Specimen 21cab01c-e968-42cc-9651-1e53c0: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 75870ca8-e949-492d-b5f8-a7108ae99517.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 8ffc3824-36ef-464a-a1e4-9e0e50 (Blood Derived Normal), aliquot 8ffc3824-36ef-464a-a1e4-9e0e50_D1_1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/30bed422-1ad1-44dc-99e4-2a3930c5e7d9

The open-access MAF lists 2,665 somatic variants for this specimen: 1,804 protein-altering or splice-affecting, 498 silent, 363 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 1,228, Silent 498, Frame Shift Del 390, Intron 225, Frame Shift Ins 67, Nonsense Mutation 62, 3'UTR 40, RNA 37, 5'UTR 26, Splice Region 26, 5'Flank 23, Splice Site 20.

Variants (750 of 2,665; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AC068580.4 | c.268dup p.Q90Pfs*50 | Frame Shift Ins (INS) | VAF 34/210 reads (16%) | catalogued as rs752612332; ClinVar: pathogenic; called by mutect2, varscan2
- APC | c.1759del p.S587Afs*3 | Frame Shift Del (DEL) | VAF 71/426 reads (17%) | catalogued as rs1554083100, CM920037, COSV57379749; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- ARAF | c.640T>C p.S214P | Missense Mutation (SNP) | VAF 23/132 reads (17%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as COSV51691221, COSV51692725, COSV51695605; called by muse, mutect2, varscan2
- B3GALT6 | c.588del p.R197Afs*81 | Frame Shift Del (DEL) | VAF 8/52 reads (15%) | catalogued as rs533071750, COSV55420617; ClinVar: pathogenic; called by mutect2, pindel
- CLCN5 | c.1039C>T p.R347* | Nonsense Mutation (SNP) | VAF 51/156 reads (33%) | catalogued as rs797044810, CM983859, COSV56582168; ClinVar: pathogenic; called by muse, mutect2, varscan2
- FOXG1 | c.460del p.E154Rfs*38 | Frame Shift Del (DEL) | VAF 32/150 reads (21%) | catalogued as rs398124204; ClinVar: pathogenic; called by mutect2, pindel
- GAA | c.2242del p.E748Rfs*16 | Frame Shift Del (DEL) | VAF 126/722 reads (17%) | catalogued as rs777275355, CM082763, CM128388, CM970554; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- GBA | c.625C>T p.R209C | Missense Mutation (SNP) | VAF 117/553 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.871); catalogued as rs398123532, CM001165; ClinVar: pathogenic; called by muse, mutect2, varscan2
- GUCY2D | c.2512C>T p.R838C | Missense Mutation (SNP) | VAF 123/702 reads (18%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as rs61750172, CM012607, CM085456, CM980959; ClinVar: pathogenic; called by muse, mutect2, varscan2
- HBB | c.328G>A p.V110M | Missense Mutation (SNP) | VAF 58/381 reads (15%) | SIFT tolerated (0.41); PolyPhen benign (0.099); catalogued as rs33969677, CD920866, CM077579, CM900317, CM930378; ClinVar: likely pathogenic / other / pathogenic; called by muse, mutect2, varscan2
- HRAS | c.179G>T p.G60V | Missense Mutation (SNP) | VAF 147/665 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs730880460, CM158178, COSV54239859; ClinVar: pathogenic; called by muse, mutect2, varscan2
- KMT2B | c.521dup p.T176Dfs*8 | Frame Shift Ins (INS) | VAF 36/165 reads (22%) | catalogued as rs763183959; ClinVar: pathogenic; called by mutect2, varscan2
- LARP7 | c.1213del p.T405Qfs*5 | Frame Shift Del (DEL) | VAF 17/37 reads (46%) | catalogued as rs750946801; ClinVar: likely pathogenic; called by mutect2, varscan2
- MAPKBP1 | c.4393C>T p.R1465* (on ENST00000456763 / NM_001128608.2; = p.R1459* on NM_014994.3) | Nonsense Mutation (SNP) | VAF 63/290 reads (22%) | catalogued as rs1057519304; ClinVar: pathogenic; called by muse, mutect2, varscan2
- MOCS2 | c.65dup p.L23Ifs*5 | Frame Shift Ins (INS) | VAF 61/354 reads (17%) | catalogued as rs398122799; ClinVar: pathogenic; called by mutect2, varscan2
- MYH11 | c.5787-4707del | Intron (DEL) | VAF 32/162 reads (20%) | catalogued as rs747392139, COSV100257523; ClinVar: uncertain significance / benign / likely benign / likely pathogenic; called by mutect2, varscan2
- NEUROD1 | c.616dup p.H206Pfs*38 | Frame Shift Ins (INS) | VAF 99/483 reads (20%) | catalogued as rs387906384; ClinVar: pathogenic; called by mutect2, varscan2
- NF1 | c.2033dup p.I679Dfs*21 | Frame Shift Ins (INS) | VAF 127/675 reads (19%) | catalogued as rs587781807; ClinVar: pathogenic; called by mutect2, varscan2
- NOD2 | c.1759C>T p.R587C | Missense Mutation (SNP) | VAF 100/536 reads (19%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as rs104895479, CM055112, COSV56054683; ClinVar: likely pathogenic / not provided; called by muse, mutect2, varscan2
- PDX1 | c.217del p.L73Sfs*50 | Frame Shift Del (DEL) | VAF 35/165 reads (21%) | catalogued as rs1445970498; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- PIK3CA | c.1633G>A p.E545K | Missense Mutation (SNP) | VAF 17/81 reads (21%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.909); catalogued as rs104886003, CM126692, COSV55873239, COSV55878227; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- RIN2 | c.1878dup p.I627Hfs*7 (on ENST00000255006 / NM_001242581.1; = p.I578Hfs*7 on NM_018993.4 and 1 other RefSeq transcript) | Frame Shift Ins (INS) | VAF 72/400 reads (18%) | catalogued as rs759390822; ClinVar: pathogenic; called by mutect2, varscan2
- SACS | c.8793del p.K2931Nfs*22 | Frame Shift Del (DEL) | VAF 46/280 reads (16%) | catalogued as rs767871841, CD056854; ClinVar: likely pathogenic / pathogenic; called by mutect2, pindel, varscan2
- SALL4 | c.2713C>T p.R905* | Nonsense Mutation (SNP) | VAF 69/328 reads (21%) | catalogued as rs74315428, CM060468, COSV99409642; ClinVar: pathogenic; called by muse, mutect2, varscan2
- SHANK3 | c.3658del p.A1220Pfs*57 | Frame Shift Del (DEL) | VAF 80/380 reads (21%) | catalogued as rs762292772; ClinVar: pathogenic; called by mutect2, varscan2
- TGFB2 | c.821del p.N274Tfs*10 | Frame Shift Del (DEL) | VAF 29/148 reads (20%) | catalogued as rs863223796; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- A2ML1 | c.1774C>T p.R592W | Missense Mutation (SNP) | VAF 17/115 reads (15%) | SIFT tolerated (0.05); PolyPhen benign (0.398); catalogued as rs748309907; called by muse, mutect2, varscan2
- AADACL3 | c.762del p.Q255Kfs*14 | Frame Shift Del (DEL) | VAF 41/223 reads (18%) | catalogued as rs746497630; called by mutect2, varscan2
- ABCA3 | c.2011C>T p.R671C | Missense Mutation (SNP) | VAF 60/662 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs183645105; ClinVar: uncertain significance; called by muse, mutect2
- ABCA7 | c.3104T>C p.L1035P | Missense Mutation (SNP) | VAF 69/369 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs560848213; called by muse, mutect2, varscan2
- ABCB9 | c.1295del p.G432Afs*9 | Frame Shift Del (DEL) | VAF 40/196 reads (20%) | catalogued as COSV54891394; called by mutect2, pindel, varscan2
- ABCC8 | c.4249C>A p.L1417M | Missense Mutation (SNP) | VAF 117/682 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56851415; called by muse, mutect2, varscan2
- ABCF3 | c.1147G>A p.D383N | Missense Mutation (SNP) | VAF 113/571 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs767126017, COSV53054204; called by muse, mutect2, varscan2
- ABRAXAS1 | c.578G>A p.R193Q | Missense Mutation (SNP) | VAF 12/53 reads (23%) | SIFT tolerated (0.18); PolyPhen benign (0.249); catalogued as rs138594808; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ACAA2 | c.41G>A p.R14Q | Missense Mutation (SNP) | VAF 47/222 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as rs746000048, COSV53271725; called by muse, mutect2, varscan2
- ACACB | c.3163G>A p.A1055T | Missense Mutation (SNP) | VAF 57/295 reads (19%) | SIFT tolerated (0.29); PolyPhen benign (0.105); catalogued as rs373113364; called by muse, mutect2, varscan2
- ACKR3 | c.166G>A p.V56I | Missense Mutation (SNP) | VAF 87/793 reads (11%) | SIFT tolerated (0.36); PolyPhen benign (0.019); catalogued as rs769053538; called by muse, mutect2, varscan2
- ACMSD | c.728G>A p.R243H | Missense Mutation (SNP) | VAF 50/231 reads (22%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.835); catalogued as rs199569492, COSV51605508, COSV51606977; called by muse, mutect2, varscan2
- ACSBG1 | c.1997G>A p.R666Q | Missense Mutation (SNP) | VAF 72/455 reads (16%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as rs142706102, COSV51910333; called by muse, mutect2, varscan2
- ACSBG2 | c.1114C>T p.R372C | Missense Mutation (SNP) | VAF 68/344 reads (20%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.93); catalogued as rs763484624, COSV53123522; called by muse, mutect2, varscan2
- ACSL5 | c.256G>A p.A86T (on ENST00000354273; = p.A142T on NM_016234.3) | Missense Mutation (SNP) | VAF 38/154 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as rs531114802, COSV61130953; called by muse, varscan2
- ACSM1 | c.1192G>A p.V398I | Missense Mutation (SNP) | VAF 32/388 reads (8%) | SIFT tolerated (0.16); PolyPhen benign (0.009); catalogued as rs376792697; called by muse, mutect2
- ACSS2 | c.806del p.P269Qfs*69 | Frame Shift Del (DEL) | VAF 30/176 reads (17%) | catalogued as rs745681981, COSV53623223; called by mutect2, pindel, varscan2
- ACTG1 | c.206A>G p.Y69C | Missense Mutation (SNP) | VAF 130/668 reads (19%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.999); catalogued as rs781953399, COSV59510388; ClinVar: uncertain significance; called by mutect2, varscan2
- ACTN1 | c.226C>T p.R76C | Missense Mutation (SNP) | VAF 43/200 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.923); catalogued as rs370008804; called by muse, mutect2, varscan2
- ACTN3 | c.1135G>A p.A379T | Missense Mutation (SNP) | VAF 57/355 reads (16%) | SIFT tolerated (0.31); PolyPhen benign (0.055); catalogued as rs778038749; called by muse, mutect2, varscan2
- ACVR2A | c.1310del p.K437Rfs*5 | Frame Shift Del (DEL) | VAF 36/102 reads (35%) | catalogued as rs764719749, COSV104385546; called by mutect2, varscan2
- ADAMDEC1 | c.1022del p.K341Rfs*7 | Frame Shift Del (DEL) | VAF 10/54 reads (19%) | catalogued as rs746174250; called by mutect2, varscan2
- ADAMTS1 | c.646G>A p.E216K | Missense Mutation (SNP) | VAF 46/203 reads (23%) | SIFT tolerated (0.89); PolyPhen benign (0); catalogued as rs886148714; called by muse, mutect2, varscan2
- ADAMTS13 | c.3977G>A p.R1326Q | Missense Mutation (SNP) | VAF 167/871 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.093); catalogued as rs782693351; called by muse, mutect2, varscan2
- ADAMTS19 | c.3575G>A p.R1192Q | Missense Mutation (SNP) | VAF 35/228 reads (15%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs1290467557, COSV50810307, COSV99176714; called by muse, mutect2, varscan2
- ADCK1 | c.403C>T p.R135* | Nonsense Mutation (SNP) | VAF 46/187 reads (25%) | catalogued as rs142770287; called by muse, mutect2, varscan2
- ADCY3 | c.1631C>T p.T544M | Missense Mutation (SNP) | VAF 45/237 reads (19%) | SIFT tolerated (0.18); PolyPhen benign (0.005); catalogued as rs200642280; called by muse, mutect2, varscan2
- ADCY5 | c.1535G>A p.R512H | Missense Mutation (SNP) | VAF 29/166 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1458350835, COSV59199228; called by muse, mutect2, varscan2
- ADCY8 | c.2716G>A p.A906T | Missense Mutation (SNP) | VAF 21/168 reads (13%) | SIFT tolerated (0.17); PolyPhen benign (0.139); catalogued as rs765905342, COSV53931186; called by muse, mutect2, varscan2
- ADNP2 | c.1301C>T p.S434L | Missense Mutation (SNP) | VAF 69/377 reads (18%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.462); catalogued as COSV104384863; called by muse, mutect2, varscan2
- ADRB3 | c.149C>T p.A50V | Missense Mutation (SNP) | VAF 56/379 reads (15%) | SIFT tolerated (0.79); PolyPhen benign (0.015); catalogued as rs201549798; called by muse, mutect2, varscan2
- AGAP2 | c.939del p.P315Lfs*14 | Frame Shift Del (DEL) | VAF 97/541 reads (18%) | catalogued as COSV57730926; called by mutect2, pindel, varscan2
- AGER | c.1102C>T p.R368C | Missense Mutation (SNP) | VAF 37/211 reads (18%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.432); catalogued as rs367834402; called by muse, mutect2, varscan2
- AGO4 | c.2009G>A p.R670H | Missense Mutation (SNP) | VAF 55/268 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1231795511, COSV64618157; called by muse, mutect2, varscan2
- AHCTF1 | c.3446T>A p.I1149N (on ENST00000366508; = p.I1123N on NM_015446.5) | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.814); catalogued as COSV100403729; called by muse, mutect2, varscan2
- AHDC1 | c.1871G>A p.R624H | Missense Mutation (SNP) | VAF 69/377 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as rs769916982; called by muse, mutect2, varscan2
- AIFM3 | c.823G>A p.V275M | Missense Mutation (SNP) | VAF 69/382 reads (18%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.671); catalogued as rs371705249; called by muse, mutect2, varscan2
- AKAP9 | c.116del p.K39Rfs*17 | Frame Shift Del (DEL) | VAF 30/143 reads (21%) | catalogued as COSV62339755; called by mutect2, varscan2
- AKT3 | c.1099C>T p.R367* | Nonsense Mutation (SNP) | VAF 46/269 reads (17%) | catalogued as COSV99028384, COSV99796929; called by muse, mutect2, varscan2
- AL136295.1 | c.1939G>A p.A647T | Missense Mutation (SNP) | VAF 56/261 reads (21%) | SIFT tolerated (0.1); PolyPhen benign (0.153); catalogued as rs575508224, COSV99937894; called by muse, mutect2, varscan2
- ALG10B | c.313G>A p.V105I | Missense Mutation (SNP) | VAF 89/539 reads (17%) | SIFT tolerated (0.34); PolyPhen benign (0.043); catalogued as COSV58142210; called by muse, mutect2, varscan2
- AMBN | c.170A>G p.N57S | Missense Mutation (SNP) | VAF 10/61 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as rs1406832446; called by muse, mutect2, varscan2
- AMOT | c.914C>T p.S305L | Missense Mutation (SNP) | VAF 67/158 reads (42%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.005); catalogued as rs1031276652, COSV100494691; called by muse, mutect2, varscan2
- AMY2A | c.832G>A p.G278S | Missense Mutation (SNP) | VAF 25/192 reads (13%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.776); catalogued as rs746422923; called by muse, mutect2, varscan2
- ANGPTL2 | c.1073C>T p.T358M | Missense Mutation (SNP) | VAF 103/582 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs752232897, COSV99400564; called by muse, mutect2, varscan2
- ANGPTL2 | c.7C>T p.P3S | Missense Mutation (SNP) | VAF 29/244 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as rs778072218, COSV52236059; called by muse, mutect2, varscan2
- ANKAR | c.3196G>A p.V1066I | Missense Mutation (SNP) | VAF 10/67 reads (15%) | SIFT tolerated (0.21); PolyPhen benign (0.425); catalogued as rs1011649076; called by muse, mutect2, varscan2
- ANKDD1B | c.1180G>A p.A394T | Missense Mutation (SNP) | VAF 39/225 reads (17%) | SIFT tolerated (0.22); PolyPhen benign (0.175); catalogued as rs1458460030, COSV72645633; called by muse, mutect2, varscan2
- ANKIB1 | c.437A>C p.N146T | Missense Mutation (SNP) | VAF 32/136 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.92); catalogued as COSV56058727; called by mutect2, varscan2
- ANKLE1 | c.1910G>A p.R637H (on ENST00000394458; = p.R583H on NM_152363.6) | Missense Mutation (SNP) | VAF 54/197 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1316256750, COSV101082280, COSV66732028; called by muse, mutect2, varscan2
- ANKLE2 | c.1091C>T p.A364V | Missense Mutation (SNP) | VAF 6/45 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.949); catalogued as rs1218415939, COSV100514275; called by muse, mutect2, varscan2
- ANKRD11 | c.548G>A p.R183H | Missense Mutation (SNP) | VAF 150/780 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV56356694; called by muse, mutect2, varscan2
- ANKRD13B | c.1228C>T p.R410C | Missense Mutation (SNP) | VAF 64/342 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.93); catalogued as rs371236478, COSV61471913; called by muse, mutect2, varscan2
- ANKRD17 | c.2078G>A p.R693H | Missense Mutation (SNP) | VAF 29/133 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1414237068; called by muse, mutect2, varscan2
- ANKRD20A1 | c.1376del p.N459Ifs*5 | Frame Shift Del (DEL) | VAF 10/31 reads (32%) | catalogued as rs1296524808; called by mutect2, varscan2
- ANKRD36 | c.4750C>T p.R1584C | Missense Mutation (SNP) | VAF 77/752 reads (10%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.967); catalogued as rs778347864, COSV100825878; called by muse, mutect2, varscan2
- ANKRD36C | c.3155G>A p.R1052H | Missense Mutation (SNP) | VAF 73/390 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.276); catalogued as rs774459798; called by muse, mutect2, varscan2
- ANPEP | c.444del p.D149Tfs*23 | Frame Shift Del (DEL) | VAF 74/420 reads (18%) | catalogued as rs766752247, COSV100263586; called by mutect2, pindel, varscan2
- AP1G1 | c.688G>A p.G230R | Missense Mutation (SNP) | VAF 28/132 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.042); catalogued as rs748009738; called by muse, mutect2, varscan2
- APBA3 | c.1561C>T p.R521C | Missense Mutation (SNP) | VAF 29/184 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1157453351; called by muse, mutect2, varscan2
- APBB1 | c.1352G>A p.R451H | Missense Mutation (SNP) | VAF 63/277 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs772042074; called by muse, mutect2, varscan2
- APC | c.4234G>T p.G1412* | Nonsense Mutation (SNP) | VAF 46/290 reads (16%) | catalogued as COSV57341688; called by muse, mutect2, varscan2
- APOB | c.1468C>T p.R490W | Missense Mutation (SNP) | VAF 95/591 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs771541567, CM031933; called by muse, mutect2, varscan2
- APOF | c.490C>T p.R164C | Missense Mutation (SNP) | VAF 90/425 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs758797440, COSV104403980; called by muse, mutect2, varscan2
- APPL2 | c.633del p.F211Lfs*28 | Frame Shift Del (DEL) | VAF 40/221 reads (18%) | catalogued as COSV51591248; called by mutect2, pindel, varscan2
- AREL1 | c.173G>A p.R58Q | Missense Mutation (SNP) | VAF 68/429 reads (16%) | SIFT tolerated (0.61); PolyPhen benign (0.396); catalogued as rs778490827; called by muse, mutect2, varscan2
- ARHGAP32 | c.193C>T p.R65W | Missense Mutation (SNP) | VAF 7/103 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs944275957, COSV100089211; called by muse, mutect2
- ARHGEF26 | c.874G>A p.A292T | Missense Mutation (SNP) | VAF 49/304 reads (16%) | SIFT tolerated (0.23); PolyPhen benign (0.001); catalogued as COSV62843490; called by muse, varscan2
- ARID4B | c.1369G>A p.D457N | Missense Mutation (SNP) | VAF 28/110 reads (25%) | SIFT tolerated, low confidence (0.73); PolyPhen benign (0); catalogued as rs759386155; called by muse, varscan2
- ARL4D | c.237dup p.Q80Afs*28 | Frame Shift Ins (INS) | VAF 123/680 reads (18%) | catalogued as rs758198899; called by mutect2, pindel, varscan2
- ARMH2 | c.136del p.I46Sfs*20 | Frame Shift Del (DEL) | VAF 46/244 reads (19%) | catalogued as rs965020534; called by mutect2, varscan2
- ASIC2 | c.1194C>T p.I398= | Splice Region (SNP) | VAF 44/237 reads (19%) | catalogued as rs767697487; called by muse, mutect2, varscan2
- ASNS | c.145C>T p.R49W | Missense Mutation (SNP) | VAF 58/432 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs111953545; called by muse, mutect2, varscan2
- ASTN2 | c.4000G>A p.G1334R (on ENST00000313400 / NM_001365069.1; = p.G1283R on NM_014010.5) | Missense Mutation (SNP) | VAF 100/491 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.819); catalogued as rs190067377, COSV99940244; called by muse, mutect2, varscan2
- ASTN2 | c.1343C>T p.A448V (on ENST00000313400 / NM_001365069.1; = p.A397V on NM_014010.5) | Missense Mutation (SNP) | VAF 21/156 reads (13%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.778); catalogued as rs989605263; called by muse, mutect2, varscan2
- ATG2B | c.3120del p.K1040Nfs*2 | Frame Shift Del (DEL) | VAF 16/112 reads (14%) | catalogued as rs771531141; called by mutect2, varscan2
- ATN1 | c.2228del p.P743Qfs*12 | Frame Shift Del (DEL) | VAF 30/144 reads (21%) | catalogued as rs1555143996; called by mutect2, pindel, varscan2
- ATP11B | c.2650del p.Y884Ifs*30 | Frame Shift Del (DEL) | VAF 17/71 reads (24%) | catalogued as rs759638000; called by mutect2, varscan2
- ATP13A1 | c.1187del p.P396Hfs*8 | Frame Shift Del (DEL) | VAF 50/292 reads (17%) | catalogued as COSV99366003; called by mutect2, pindel, varscan2
- ATP1A3 | c.1804G>A p.V602I (on ENST00000545399 / NM_001256214.2; = p.V589I on NM_152296.5) | Missense Mutation (SNP) | VAF 132/632 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV57487073; called by muse, mutect2, varscan2
- ATP1A4 | c.69del p.I26Sfs*6 | Frame Shift Del (DEL) | VAF 17/133 reads (13%) | catalogued as rs1467294583; called by mutect2, pindel, varscan2
- ATP1A4 | c.1072C>T p.R358C | Missense Mutation (SNP) | VAF 53/316 reads (17%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as rs746192251; called by muse, mutect2, varscan2
- ATP2C2 | c.629C>T p.T210M | Missense Mutation (SNP) | VAF 34/123 reads (28%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.99); catalogued as rs202138543; called by muse, mutect2, varscan2
- ATP9B | c.2705C>T p.A902V | Missense Mutation (SNP) | VAF 21/103 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs752764821, COSV56952702; called by muse, mutect2, varscan2
- ATXN1 | c.1135C>T p.R379W | Missense Mutation (SNP) | VAF 95/545 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1482070456, COSV55209847; called by muse, mutect2, varscan2
- ATXN1L | c.1483C>T p.R495C | Missense Mutation (SNP) | VAF 28/298 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as rs1313192823; called by muse, mutect2
- ATXN2L | c.2258C>T p.P753L | Missense Mutation (SNP) | VAF 56/257 reads (22%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.886); catalogued as rs762176848, COSV57369593; called by muse, mutect2, varscan2
- B4GALT2 | c.21del p.T8Rfs*102 | Frame Shift Del (DEL) | VAF 70/479 reads (15%) | catalogued as rs759490732, COSV99356264; called by mutect2, pindel, varscan2
- BABAM2 | c.488del p.N163Tfs*13 | Frame Shift Del (DEL) | VAF 9/35 reads (26%) | catalogued as COSV59620972; called by mutect2, varscan2
- BAG6 | c.1169dup p.T391Nfs*29 | Frame Shift Ins (INS) | VAF 24/134 reads (18%) | catalogued as rs745882580; called by mutect2, varscan2
- BAHCC1 | c.1552del p.Q518Rfs*6 | Frame Shift Del (DEL) | VAF 134/665 reads (20%) | catalogued as COSV57032887; called by mutect2, pindel, varscan2
- BAHCC1 | c.4340C>T p.A1447V | Missense Mutation (SNP) | VAF 23/61 reads (38%) | SIFT deleterious (0.05); PolyPhen benign (0.391); catalogued as rs781824711; called by muse, mutect2, varscan2
- BARD1 | c.1949del p.K650Sfs*64 | Frame Shift Del (DEL) | VAF 50/300 reads (17%) | catalogued as COSV53610550; called by mutect2, pindel, varscan2
- BAZ2A | c.5473C>T p.R1825C | Missense Mutation (SNP) | VAF 43/272 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs751270221; called by muse, mutect2, varscan2
- BCAM | c.1738C>T p.R580C | Missense Mutation (SNP) | VAF 47/144 reads (33%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as rs376176106; called by muse, mutect2, varscan2
- BCL7A | c.130C>T p.R44* | Nonsense Mutation (SNP) | VAF 48/280 reads (17%) | catalogued as COSV55848938; called by muse, mutect2, varscan2
- BCORL1 | c.5042del p.P1681Qfs*20 | Frame Shift Del (DEL) | VAF 68/185 reads (37%) | catalogued as rs768244116; called by mutect2, pindel, varscan2
- BEAN1 | c.284G>A p.G95D | Missense Mutation (SNP) | VAF 76/394 reads (19%) | SIFT tolerated (0.25); PolyPhen benign (0.001); catalogued as rs1346996808; called by muse, mutect2, varscan2
- BEST3 | c.1382C>T p.T461M | Missense Mutation (SNP) | VAF 80/518 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.092); catalogued as rs750674581, COSV58302493; called by muse, mutect2, varscan2
- BIN3 | c.338del p.K113Sfs*13 | Frame Shift Del (DEL) | VAF 38/178 reads (21%) | catalogued as rs776003776; called by mutect2, pindel, varscan2
- BIRC6 | c.11999G>A p.R4000H | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT tolerated (0.2); PolyPhen benign (0.009); catalogued as rs749892925; called by mutect2, varscan2
- BMPR2 | c.1748del p.N583Tfs*44 | Frame Shift Del (DEL) | VAF 28/182 reads (15%) | catalogued as rs772920507, COSV65808737; called by mutect2, pindel, varscan2
- BRI3 | c.346C>T p.R116* | Nonsense Mutation (SNP) | VAF 36/192 reads (19%) | catalogued as rs773385746, COSV50060873; called by muse, mutect2, varscan2
- BRWD1 | c.6926del p.L2309* | Frame Shift Del (DEL) | VAF 42/124 reads (34%) | catalogued as rs1455506786, COSV59000653; called by mutect2, pindel, varscan2
- BTBD11 | c.1357del p.L453Cfs*53 | Frame Shift Del (DEL) | VAF 100/328 reads (30%) | catalogued as rs777776928; called by mutect2, varscan2
- C11orf95 | c.193del p.L65Cfs*50 | Frame Shift Del (DEL) | VAF 9/57 reads (16%) | catalogued as rs1284173834; called by mutect2, pindel, varscan2
- C17orf49 | c.244C>T p.R82C | Missense Mutation (SNP) | VAF 11/84 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs201799608, COSV101143341; called by muse, mutect2, varscan2
- C19orf38 | c.61C>T p.R21W | Missense Mutation (SNP) | VAF 62/256 reads (24%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as rs975583165; called by muse, mutect2, varscan2
- C1QTNF9 | c.788A>G p.Q263R | Missense Mutation (SNP) | VAF 20/200 reads (10%) | SIFT tolerated (1); PolyPhen benign (0.012); catalogued as rs1428821451; called by muse, mutect2, varscan2
- C1orf112 | c.260G>A p.S87N | Missense Mutation (SNP) | VAF 29/164 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.892); catalogued as COSV53676942; called by muse, mutect2, varscan2
- C1orf167 | c.4147G>A p.A1383T | Missense Mutation (SNP) | VAF 24/229 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as rs1453082525; called by muse, mutect2
- C20orf85 | c.269del p.P90Qfs*19 | Frame Shift Del (DEL) | VAF 36/172 reads (21%) | catalogued as rs777635732, COSV100959338, COSV64519981; called by mutect2, varscan2
- C2orf78 | c.2047G>T p.G683C | Missense Mutation (SNP) | VAF 54/255 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.022); catalogued as COSV68516290; called by muse, mutect2, varscan2
- C3 | c.2564G>A p.R855Q | Missense Mutation (SNP) | VAF 183/847 reads (22%) | SIFT tolerated (0.65); PolyPhen benign (0.035); catalogued as rs199784156, COSV99837128; called by muse, mutect2, varscan2
- C4orf47 | c.8C>T p.A3V | Missense Mutation (SNP) | VAF 12/72 reads (17%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.001); catalogued as rs752707291; called by muse, mutect2, varscan2
- C6orf47 | c.481del p.E161Nfs*22 | Frame Shift Del (DEL) | VAF 50/376 reads (13%) | catalogued as rs1396655057; called by mutect2, varscan2
- C6orf89 | c.728G>A p.R243H (on ENST00000373685; = p.R250H on NM_152734.4) | Missense Mutation (SNP) | VAF 35/192 reads (18%) | SIFT tolerated (0.53); PolyPhen benign (0.001); catalogued as rs144834171; called by muse, mutect2, varscan2
- C7orf50 | c.535del p.L179Cfs*136 | Frame Shift Del (DEL) | VAF 30/202 reads (15%) | catalogued as rs750339990; called by mutect2, pindel, varscan2
- CACNA1D | c.28del p.M10Cfs*60 | Frame Shift Del (DEL) | VAF 185/564 reads (33%) | catalogued as COSV55457798; called by mutect2, pindel, varscan2
- CACNA1H | c.1460G>A p.R487H | Missense Mutation (SNP) | VAF 70/356 reads (20%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as rs545918011; called by muse, mutect2, varscan2
- CACNA1I | c.4714G>A p.E1572K | Missense Mutation (SNP) | VAF 34/223 reads (15%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as COSV100358871; called by muse, mutect2, varscan2
- CACNA2D3 | c.2941A>G p.T981A | Missense Mutation (SNP) | VAF 41/283 reads (14%) | SIFT tolerated (0.75); PolyPhen benign (0.01); catalogued as COSV99878655; called by muse, varscan2
- CACNG2 | c.762del p.V255Wfs*24 | Frame Shift Del (DEL) | VAF 97/545 reads (18%) | catalogued as COSV55632942; called by mutect2, pindel, varscan2
- CACNG6 | c.704C>T p.A235V (on ENST00000252729 / NM_145814.1; = p.A164V on NM_031897.2) | Missense Mutation (SNP) | VAF 22/125 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.179); catalogued as COSV53167350, COSV99403560; called by muse, mutect2, varscan2
- CACNG7 | c.269C>T p.T90M | Missense Mutation (SNP) | VAF 22/186 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs764997446, COSV99712133; called by muse, mutect2, varscan2
- CADM1 | c.179C>T p.A60V | Missense Mutation (SNP) | VAF 77/436 reads (18%) | SIFT tolerated (0.76); PolyPhen possibly damaging (0.683); catalogued as rs986045773, COSV59017228; called by muse, mutect2, varscan2
- CADM3 | c.940C>A p.L314I (on ENST00000368125 / NM_001127173.3; = p.L348I on NM_021189.5) | Missense Mutation (SNP) | VAF 27/241 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV63685514; called by muse, mutect2, varscan2
- CALCOCO1 | c.1669C>T p.R557C | Missense Mutation (SNP) | VAF 22/82 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0.326); catalogued as rs772520577; called by muse, mutect2, varscan2
- CALD1 | c.116G>A p.R39Q | Missense Mutation (SNP) | VAF 29/194 reads (15%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.998); catalogued as rs371342595; called by muse, mutect2, varscan2
- CAMSAP1 | c.3016C>A p.L1006I | Missense Mutation (SNP) | VAF 56/345 reads (16%) | SIFT tolerated (0.38); PolyPhen benign (0.427); catalogued as rs1186635377; called by muse, mutect2, varscan2
- CAMSAP3 | c.1307del p.G436Afs*127 | Frame Shift Del (DEL) | VAF 29/138 reads (21%) | catalogued as COSV50370548; called by mutect2, pindel, varscan2
- CAMTA2 | c.388C>T p.R130W | Missense Mutation (SNP) | VAF 31/173 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1192398915, COSV61834894; called by muse, mutect2, varscan2
- CAND1 | c.2422C>T p.R808* | Nonsense Mutation (SNP) | VAF 63/353 reads (18%) | catalogued as COSV101607321; called by muse, mutect2, varscan2
- CAPZA1 | c.77del p.P26Qfs*40 | Frame Shift Del (DEL) | VAF 12/47 reads (26%) | catalogued as COSV54147680; called by mutect2, pindel, varscan2
- CARD14 | c.2888C>T p.A963V | Missense Mutation (SNP) | VAF 30/296 reads (10%) | SIFT tolerated (0.93); PolyPhen benign (0); catalogued as rs1176488460; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CASKIN1 | c.277G>T p.G93C | Missense Mutation (SNP) | VAF 102/370 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58877558, COSV58877677; called by muse, mutect2, varscan2
- CASP7 | c.375del p.A126Lfs*17 | Frame Shift Del (DEL) | VAF 38/221 reads (17%) | catalogued as rs1247046723, COSV61881818; called by pindel, varscan2
- CAV3 | c.7G>A p.A3T | Missense Mutation (SNP) | VAF 228/584 reads (39%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.843); catalogued as rs1291499448; called by muse, varscan2
- CBARP | c.1405G>A p.A469T | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as rs1194502895; called by muse, mutect2, varscan2
- CBLN2 | c.332G>A p.R111H | Missense Mutation (SNP) | VAF 54/273 reads (20%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.909); catalogued as COSV54051619; called by muse, mutect2, varscan2
- CCDC120 | c.1067G>A p.R356H | Missense Mutation (SNP) | VAF 67/192 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs782019146; called by muse, mutect2, varscan2
- CCDC136 | c.146G>A p.R49Q | Missense Mutation (SNP) | VAF 74/420 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV52800620; called by muse, mutect2, varscan2
- CCDC142 | c.1803G>T p.Q601H (on ENST00000393965 / NM_001365575.2; = p.Q594H on NM_032779.4) | Missense Mutation (SNP) | VAF 71/275 reads (26%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.997); catalogued as COSV50688311; called by muse, mutect2, varscan2
- CCDC170 | c.1496G>A p.S499N | Missense Mutation (SNP) | VAF 18/64 reads (28%) | SIFT deleterious (0.05); PolyPhen probably damaging (1); catalogued as rs1376221899; called by muse, varscan2
- CCDC40 | c.2935C>T p.R979C | Missense Mutation (SNP) | VAF 208/547 reads (38%) | SIFT tolerated (0.07); PolyPhen benign (0.356); catalogued as rs774907489, COSV100884295, COSV100884364; called by muse, mutect2, varscan2
- CCDC74B | c.841G>A p.E281K | Missense Mutation (SNP) | VAF 91/533 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.026); catalogued as rs757926667, COSV60100706; called by muse, mutect2, varscan2
- CCDC80 | c.392G>A p.R131H | Missense Mutation (SNP) | VAF 152/826 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1400184415, COSV52816425; called by muse, mutect2, varscan2
- CCDC88C | c.2969C>T p.A990V | Missense Mutation (SNP) | VAF 45/243 reads (19%) | SIFT tolerated (0.47); PolyPhen benign (0); catalogued as rs201174781; called by muse, mutect2, varscan2
- CCNT1 | c.58G>A p.E20K | Missense Mutation (SNP) | VAF 15/114 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.59); catalogued as rs367772894; called by muse, mutect2, varscan2
- CCZ1B | c.946G>A p.V316I | Missense Mutation (SNP) | VAF 26/205 reads (13%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.733); catalogued as rs372795611; called by muse, mutect2, varscan2
- CD163L1 | c.2204C>T p.S735F | Missense Mutation (SNP) | VAF 83/535 reads (16%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.987); catalogued as rs767732906; called by muse, mutect2, varscan2
- CD6 | c.714G>A p.W238* | Nonsense Mutation (SNP) | VAF 34/191 reads (18%) | catalogued as rs1360124086; called by muse, mutect2, varscan2
- CD82 | c.529G>A p.E177K | Missense Mutation (SNP) | VAF 161/871 reads (18%) | SIFT tolerated (0.92); PolyPhen benign (0.003); catalogued as rs370975589, COSV57035345; called by muse, mutect2, varscan2
- CDC7 | c.92del p.N31Tfs*51 | Frame Shift Del (DEL) | VAF 32/120 reads (27%) | catalogued as rs762194001; called by mutect2, varscan2
- CDH2 | c.154G>A p.G52R | Missense Mutation (SNP) | VAF 23/120 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99297920; called by muse, varscan2
- CDH22 | c.964A>G p.S322G | Missense Mutation (SNP) | VAF 56/326 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.011); catalogued as rs774356645, COSV64836824; called by muse, mutect2, varscan2
- CDH23 | c.8744G>A p.R2915H | Missense Mutation (SNP) | VAF 30/152 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.748); catalogued as rs58875306, COSV56452556; called by muse, mutect2, varscan2
- CDH7 | c.346G>A p.A116T | Missense Mutation (SNP) | VAF 45/441 reads (10%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.883); catalogued as rs774247887; called by muse, mutect2, varscan2
- CDHR1 | c.610C>T p.R204W | Missense Mutation (SNP) | VAF 139/735 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.97); catalogued as rs781263335, COSV100258797; called by muse, mutect2, varscan2
- CDK20 | c.955dup p.H319Pfs*4 (on ENST00000325303 / NM_001039803.3; = p.H298Pfs*4 on NM_012119.4) | Frame Shift Ins (INS) | VAF 26/178 reads (15%) | catalogued as rs749463697; called by mutect2, varscan2
- CDON | c.2092G>A p.V698I | Missense Mutation (SNP) | VAF 34/296 reads (11%) | SIFT tolerated (0.38); PolyPhen benign (0.015); catalogued as rs540592065; called by muse, mutect2, varscan2
- CEBPE | c.652G>A p.V218M | Missense Mutation (SNP) | VAF 139/747 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99247482; called by muse, mutect2, varscan2
- CEL | c.1777G>C p.A593P (on ENST00000673714; = p.A590P on NM_001807.6) | Missense Mutation (SNP) | VAF 38/192 reads (20%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.029); catalogued as rs539532953, COSV60827171; called by mutect2, varscan2
- CELSR1 | c.3682G>A p.V1228M | Missense Mutation (SNP) | VAF 80/548 reads (15%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.765); catalogued as rs763305091; called by muse, mutect2, varscan2
- CELSR1 | c.1976C>T p.A659V | Missense Mutation (SNP) | VAF 87/471 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.954); catalogued as rs1345820610, COSV53100528; called by muse, mutect2, varscan2
- CENPC | c.781del p.S261Vfs*7 | Frame Shift Del (DEL) | VAF 12/103 reads (12%) | catalogued as COSV56621209; called by mutect2, pindel, varscan2
- CENPC | c.616del p.R206Gfs*2 | Frame Shift Del (DEL) | VAF 7/34 reads (21%) | catalogued as rs1325731082; called by mutect2, pindel
- CEP170B | c.1574C>T p.P525L (on ENST00000453495; = p.P454L on NM_015005.3) | Missense Mutation (SNP) | VAF 55/294 reads (19%) | SIFT tolerated (0.08); PolyPhen benign (0.312); catalogued as rs900137573; called by muse, mutect2, varscan2
- CEP295 | c.1400C>T p.S467L | Missense Mutation (SNP) | VAF 20/120 reads (17%) | SIFT tolerated (0.65); PolyPhen benign (0.01); catalogued as rs933177823, COSV57352899; called by muse, mutect2, varscan2
- CEP63 | c.1388G>A p.R463H | Missense Mutation (SNP) | VAF 15/62 reads (24%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0); catalogued as rs759286009; called by muse, mutect2, varscan2
- CFAP20 | c.488G>A p.R163Q | Missense Mutation (SNP) | VAF 31/175 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.85); catalogued as rs1447080456; called by muse, mutect2, varscan2
- CHAF1A | c.1223G>A p.R408H | Missense Mutation (SNP) | VAF 35/152 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs146591895; called by muse, mutect2, varscan2
- CHCHD5 | c.289C>T p.R97C | Missense Mutation (SNP) | VAF 124/672 reads (18%) | SIFT tolerated (0.1); PolyPhen benign (0.052); catalogued as rs367672047; called by muse, mutect2, varscan2
- CHD5 | c.2195C>T p.T732M | Missense Mutation (SNP) | VAF 32/149 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99315794; called by muse, mutect2, varscan2
- CHGB | c.1721del p.K574Sfs*7 | Frame Shift Del (DEL) | VAF 43/274 reads (16%) | catalogued as COSV66760107; called by mutect2, pindel, varscan2
- CHIA | c.1234G>A p.G412R (on ENST00000343320; = p.G304R on NM_021797.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 105/443 reads (24%) | SIFT tolerated (0.19); PolyPhen benign (0.177); catalogued as rs941237426, COSV100588889; called by muse, mutect2, varscan2
- CHMP7 | c.454G>A p.A152T | Missense Mutation (SNP) | VAF 35/99 reads (35%) | SIFT deleterious (0.05); PolyPhen benign (0.076); catalogued as rs1224558994; called by muse, mutect2, varscan2
- CHST3 | c.307G>A p.V103M | Missense Mutation (SNP) | VAF 117/600 reads (20%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.003); catalogued as rs201211046, COSV64150404; called by muse, mutect2, varscan2
- CHST8 | c.394G>A p.A132T | Missense Mutation (SNP) | VAF 64/329 reads (19%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as rs898608902, COSV99381775; called by muse, mutect2, varscan2
- CIAO1 | c.929C>T p.A310V | Missense Mutation (SNP) | VAF 66/632 reads (10%) | SIFT tolerated (0.22); PolyPhen benign (0.218); catalogued as COSV55531399; called by muse, mutect2
- CIC | c.4234C>T p.R1412C | Missense Mutation (SNP) | VAF 226/1048 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1482300580; called by muse, mutect2, varscan2
- CIC | c.4660G>A p.A1554T | Missense Mutation (SNP) | VAF 67/287 reads (23%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.009); catalogued as rs762480443; called by muse, mutect2, varscan2
- CIT | c.2818C>T p.R940C | Missense Mutation (SNP) | VAF 11/83 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV99951377; called by muse, mutect2, varscan2
- CKLF | c.447dup p.E150Rfs*12 (on ENST00000264001 / NM_016951.4; = p.E65Rfs*12 on NM_016326.3) | Frame Shift Ins (INS) | VAF 58/279 reads (21%) | catalogued as rs754415052; called by mutect2, varscan2
- CLCN2 | c.2641C>T p.R881C | Missense Mutation (SNP) | VAF 176/727 reads (24%) | SIFT tolerated (0.11); PolyPhen benign (0.001); catalogued as rs753882107, COSV99658933; called by muse, mutect2, varscan2
- CLCN2 | c.829C>T p.R277W | Missense Mutation (SNP) | VAF 129/747 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99658703; called by muse, mutect2, varscan2
- CLMP | c.54del p.T19Lfs*45 | Frame Shift Del (DEL) | VAF 9/73 reads (12%) | catalogued as COSV71650328; called by mutect2, pindel, varscan2
- CLOCK | c.368del p.L123* | Frame Shift Del (DEL) | VAF 34/122 reads (28%) | catalogued as rs369752219; called by mutect2, varscan2
- CLTC | c.662G>A p.R221Q | Missense Mutation (SNP) | VAF 12/61 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.089); catalogued as COSV52247843; called by muse, mutect2, varscan2
- CLUH | c.1331C>T p.A444V (on ENST00000435359; = p.A482V on NM_015229.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 57/323 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV70929427; called by muse, varscan2
- CMYA5 | c.1150G>A p.D384N | Missense Mutation (SNP) | VAF 76/399 reads (19%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as rs765799270, COSV101484133; called by muse, mutect2, varscan2
- CNGA3 | c.661C>T p.R221* | Nonsense Mutation (SNP) | VAF 122/834 reads (15%) | catalogued as rs770713600, CM045042; called by muse, mutect2, varscan2
- CNTN6 | c.1253del p.K418Sfs*63 | Frame Shift Del (DEL) | VAF 16/87 reads (18%) | catalogued as rs758676375; called by mutect2, varscan2
- CNTNAP1 | c.3173G>A p.R1058H | Missense Mutation (SNP) | VAF 98/510 reads (19%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as rs766128262, COSV52850726; called by muse, mutect2, varscan2
- COL11A1 | c.1350+1G>C p.X450_splice | Splice Site (SNP) | VAF 17/126 reads (13%) | catalogued as COSV100617330, COSV62196797; called by muse, mutect2, varscan2
- COL13A1 | c.478G>A p.G160S | Missense Mutation (SNP) | VAF 67/365 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.683); catalogued as rs745996403; called by muse, mutect2, varscan2
- COL17A1 | c.978C>T p.A326= | Splice Region (SNP) | VAF 71/450 reads (16%) | catalogued as rs377503745; called by muse, mutect2, varscan2
- COL19A1 | c.2920G>T p.G974C | Missense Mutation (SNP) | VAF 41/251 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59568007; called by muse, varscan2
- COL2A1 | c.1147C>T p.R383C | Missense Mutation (SNP) | VAF 104/551 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1287418521; called by muse, mutect2, varscan2
- COL6A1 | c.2191C>T p.R731C | Missense Mutation (SNP) | VAF 47/845 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs398123635; ClinVar: likely benign / uncertain significance; called by muse, mutect2
- CORO2A | c.1006G>A p.E336K | Missense Mutation (SNP) | VAF 46/305 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs772266826; called by muse, mutect2, varscan2
- CPT2 | c.340+1G>A p.X114_splice | Splice Site (SNP) | VAF 63/396 reads (16%) | catalogued as CS134111; called by muse, mutect2, varscan2
- CPXM1 | c.548G>A p.R183H | Missense Mutation (SNP) | VAF 72/390 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as rs1409948765; called by muse, mutect2, varscan2
- CPXM2 | c.1679G>A p.R560H | Missense Mutation (SNP) | VAF 40/270 reads (15%) | SIFT tolerated (0.54); PolyPhen possibly damaging (0.767); catalogued as rs559678940, COSV53870304; called by muse, mutect2, varscan2
- CPZ | c.1940G>A p.R647H (on ENST00000360986 / NM_001014447.3; = p.R636H on NM_003652.3) | Missense Mutation (SNP) | VAF 12/61 reads (20%) | SIFT tolerated (0.4); PolyPhen benign (0.006); catalogued as rs755483835, COSV59922939; called by muse, mutect2, varscan2
- CR2 | c.1390C>T p.P464S | Missense Mutation (SNP) | VAF 176/1071 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs41313740; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CRB1 | c.3098C>T p.T1033I | Missense Mutation (SNP) | VAF 105/531 reads (20%) | SIFT tolerated (0.24); PolyPhen benign (0.003); catalogued as rs778604058, COSV66329767, COSV99054415; called by muse, mutect2, varscan2
- CREBBP | c.2365G>A p.A789T | Missense Mutation (SNP) | VAF 113/587 reads (19%) | SIFT tolerated, low confidence (0.88); PolyPhen benign (0.02); catalogued as rs746728741; called by muse, mutect2, varscan2
- CRX | c.590del p.P197Rfs*22 | Frame Shift Del (DEL) | VAF 48/256 reads (19%) | catalogued as CD972156, COSV99704356; called by mutect2, pindel, varscan2
- CRYBB2 | c.208G>A p.E70K | Missense Mutation (SNP) | VAF 157/732 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs961499964; called by muse, mutect2, varscan2
- CSF2RA | c.679C>T p.R227C | Missense Mutation (SNP) | VAF 91/583 reads (16%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as rs772324282, COSV100818018; called by muse, mutect2, varscan2
- CSF3R | c.356C>T p.A119V | Missense Mutation (SNP) | VAF 86/455 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs964612219; called by muse, mutect2, varscan2
- CSNK1G3 | c.805C>T p.R269W | Missense Mutation (SNP) | VAF 14/144 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs1340519639; called by muse, mutect2, varscan2
- CSPG4 | c.4690G>A p.E1564K | Missense Mutation (SNP) | VAF 110/586 reads (19%) | SIFT tolerated (0.25); PolyPhen benign (0.005); catalogued as rs746897054; called by muse, mutect2, varscan2
- CSPG4 | c.3517C>T p.R1173C | Missense Mutation (SNP) | VAF 70/362 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.328); catalogued as rs930788776; called by muse, mutect2, varscan2
- CSPG4 | c.1579C>T p.R527W | Missense Mutation (SNP) | VAF 110/661 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.035); catalogued as rs765993758; called by muse, mutect2, varscan2
- CTNNA1 | c.2012C>T p.A671V | Missense Mutation (SNP) | VAF 19/123 reads (15%) | SIFT tolerated (0.18); PolyPhen benign (0.024); catalogued as rs773758649; called by muse, mutect2, varscan2
- CUL1 | c.1447G>A p.D483N | Missense Mutation (SNP) | VAF 16/164 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.31); catalogued as COSV57388811; called by muse, mutect2
- CUL7 | c.2878C>T p.R960C | Missense Mutation (SNP) | VAF 178/826 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs753131991, COSV54820288; called by muse, mutect2, varscan2
- CWF19L2 | c.287del p.K96Rfs*41 | Frame Shift Del (DEL) | VAF 8/56 reads (14%) | catalogued as rs772257590; called by mutect2, varscan2
- CYHR1 | c.431G>A p.R144H | Missense Mutation (SNP) | VAF 111/514 reads (22%) | SIFT tolerated (0.07); PolyPhen benign (0.397); catalogued as rs370372984; called by muse, mutect2, varscan2
- CYP24A1 | c.1442G>A p.R481H | Missense Mutation (SNP) | VAF 130/729 reads (18%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.931); catalogued as rs774497530; called by muse, mutect2, varscan2
- CYP3A43 | c.647del p.L216Wfs*7 | Frame Shift Del (DEL) | VAF 19/89 reads (21%) | catalogued as rs779975576; called by pindel, varscan2
- CYREN | c.389del p.G130Vfs*19 | Frame Shift Del (DEL) | VAF 65/418 reads (16%) | catalogued as rs753942205; called by mutect2, pindel, varscan2
- DAPK1 | c.2155C>T p.R719C | Missense Mutation (SNP) | VAF 78/526 reads (15%) | SIFT tolerated (0.07); PolyPhen benign (0.432); catalogued as rs757064991; called by muse, mutect2, varscan2
- DBN1 | c.1007G>A p.R336Q | Missense Mutation (SNP) | VAF 19/128 reads (15%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.728); catalogued as rs144418852; called by muse, mutect2, varscan2
- DCBLD1 | c.739C>T p.R247* | Nonsense Mutation (SNP) | VAF 22/202 reads (11%) | catalogued as rs751978708; called by muse, mutect2, varscan2
- DCHS2 | c.844G>A p.V282M | Missense Mutation (SNP) | VAF 76/319 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1450378311; called by muse, mutect2, varscan2
- DCT | c.698G>A p.R233Q | Missense Mutation (SNP) | VAF 28/97 reads (29%) | SIFT tolerated (0.1); PolyPhen benign (0.068); catalogued as rs143672390; called by muse, mutect2, varscan2
- DCTN4 | c.1229G>A p.R410H | Missense Mutation (SNP) | VAF 53/355 reads (15%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as rs369286421; called by muse, mutect2, varscan2
- DDX18 | c.932G>A p.R311H | Missense Mutation (SNP) | VAF 65/376 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.881); catalogued as COSV99604552; called by muse, mutect2, varscan2
- DDX47 | c.964G>A p.V322I | Missense Mutation (SNP) | VAF 26/138 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs373242027; called by muse, varscan2
- DDX5 | c.1480C>T p.R494W | Missense Mutation (SNP) | VAF 23/131 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.844); catalogued as rs781795667, COSV56748849; called by muse, mutect2
- DEAF1 | c.1525C>T p.R509W | Missense Mutation (SNP) | VAF 95/502 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.039); catalogued as rs368021470; called by muse, mutect2, varscan2
- DECR2 | c.296A>G p.Q99R | Missense Mutation (SNP) | VAF 22/131 reads (17%) | SIFT tolerated (0.2); PolyPhen benign (0.242); catalogued as rs150350411; called by muse, mutect2, varscan2
- DENND4A | c.1000C>T p.R334C | Missense Mutation (SNP) | VAF 35/182 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1470639136, COSV71266608; called by muse, mutect2, varscan2
- DENND4C | c.2684G>T p.R895M | Missense Mutation (SNP) | VAF 16/108 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs1301524482; called by muse, mutect2, varscan2
- DGKA | c.2176del p.R726Afs*9 | Frame Shift Del (DEL) | VAF 36/166 reads (22%) | catalogued as COSV59384233; called by mutect2, varscan2
- DHRS3 | c.811G>A p.V271I | Missense Mutation (SNP) | VAF 26/146 reads (18%) | SIFT tolerated (0.26); PolyPhen benign (0.001); catalogued as rs202124062, COSV66108230; called by muse, mutect2, varscan2
- DHRS7B | c.5T>G p.V2G | Missense Mutation (SNP) | VAF 10/96 reads (10%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.029); catalogued as rs965147589; called by mutect2, varscan2
- DIAPH1 | c.3425G>A p.R1142Q | Missense Mutation (SNP) | VAF 126/691 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.287); catalogued as rs200419320, COSV53883327; called by muse, mutect2, varscan2
- DIP2A | c.146A>G p.Y49C | Missense Mutation (SNP) | VAF 20/102 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.042); catalogued as rs756236572; called by muse, mutect2, varscan2
- DLGAP3 | c.2198C>T p.T733M | Missense Mutation (SNP) | VAF 43/220 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as rs1217266034, COSV99029982; called by muse, mutect2, varscan2
- DMD | c.9930G>T p.Q3310H | Missense Mutation (SNP) | VAF 79/193 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58918400; called by muse, mutect2, varscan2
- DMWD | c.1235C>T p.S412L | Missense Mutation (SNP) | VAF 60/295 reads (20%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as rs201189607; called by muse, mutect2, varscan2
- DMXL2 | c.2650C>T p.R884C | Missense Mutation (SNP) | VAF 14/94 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.852); catalogued as rs199765814; called by muse, varscan2
- DNA2 | c.2335del p.S779Hfs*6 | Frame Shift Del (DEL) | VAF 10/62 reads (16%) | catalogued as rs745893364; called by mutect2, varscan2
- DNAH10 | c.305G>A p.R102H (on ENST00000409039; = p.R41H on NM_207437.3) | Missense Mutation (SNP) | VAF 36/184 reads (20%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.001); catalogued as rs775604149, COSV101292293, COSV68988181; called by muse, mutect2, varscan2
- DNAH17 | c.11491C>T p.R3831C | Missense Mutation (SNP) | VAF 37/212 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs778075454, COSV67758754; called by muse, mutect2, varscan2
- DNAH2 | c.11786T>C p.I3929T | Missense Mutation (SNP) | VAF 20/146 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as rs777514853; called by muse, mutect2, varscan2
- DNAH7 | c.3865C>T p.R1289* | Nonsense Mutation (SNP) | VAF 21/117 reads (18%) | catalogued as rs1278736038, COSV56778453; called by muse, mutect2, varscan2
- DNAH9 | c.7453T>C p.S2485P | Missense Mutation (SNP) | VAF 161/822 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as rs1472084028; called by muse, mutect2, varscan2
- DNAJC10 | c.622C>T p.R208W | Missense Mutation (SNP) | VAF 26/121 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.847); catalogued as rs372451587, COSV51135757; called by muse, mutect2, varscan2
- DNMT1 | c.973C>T p.R325C | Missense Mutation (SNP) | VAF 21/124 reads (17%) | SIFT tolerated (0.18); PolyPhen benign (0.425); catalogued as rs1361695976; called by muse, mutect2, varscan2
- DOCK3 | c.5555del p.P1852Qfs*45 | Frame Shift Del (DEL) | VAF 74/224 reads (33%) | catalogued as rs782552436; called by mutect2, pindel, varscan2
- DPYD | c.1042G>A p.A348T | Missense Mutation (SNP) | VAF 57/342 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.76); catalogued as CD004677; called by muse, mutect2, varscan2
- DRC1 | c.1391G>A p.R464H | Missense Mutation (SNP) | VAF 41/247 reads (17%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as rs200271366; called by muse, mutect2, varscan2
- DRD3 | c.653G>T p.R218M | Missense Mutation (SNP) | VAF 52/235 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.864); catalogued as COSV55681169; called by muse, mutect2, varscan2
- DRD5 | c.749G>A p.R250H | Missense Mutation (SNP) | VAF 44/499 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as rs1455399894, COSV58578463; called by muse, mutect2
- DROSHA | c.2482del p.I828Yfs*7 | Frame Shift Del (DEL) | VAF 16/109 reads (15%) | catalogued as rs1471632102; called by mutect2, pindel, varscan2
- DSE | c.290G>A p.R97H | Missense Mutation (SNP) | VAF 64/571 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.965); catalogued as rs534459729, COSV59067469; called by muse, mutect2, varscan2
- DSTN | c.308del p.L103Cfs*6 | Frame Shift Del (DEL) | VAF 15/68 reads (22%) | catalogued as rs750962255; called by mutect2, varscan2
- DUSP12 | c.713G>A p.R238H | Missense Mutation (SNP) | VAF 12/72 reads (17%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as rs369447270; called by muse, mutect2, varscan2
- DVL2 | c.1632del p.W545Gfs*136 | Frame Shift Del (DEL) | VAF 27/149 reads (18%) | catalogued as COSV50035838; called by mutect2, pindel, varscan2
- DYRK1A | c.1675C>T p.R559C | Missense Mutation (SNP) | VAF 19/78 reads (24%) | SIFT tolerated, low confidence (0.14); PolyPhen probably damaging (0.973); catalogued as rs757222616, COSV58703632; called by muse, mutect2, varscan2
- DYSF | c.617C>T p.A206V | Missense Mutation (SNP) | VAF 166/923 reads (18%) | SIFT tolerated (0.26); PolyPhen benign (0.094); catalogued as rs749901429, COSV50451196; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- E2F7 | c.2722G>A p.G908S | Missense Mutation (SNP) | VAF 26/157 reads (17%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.001); catalogued as COSV59739053; called by muse, mutect2, varscan2
- EEF1AKNMT | c.1094G>T p.G365V (on ENST00000361735 / NM_015935.5; = p.G279V on NM_014955.3) | Missense Mutation (SNP) | VAF 23/167 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.813); catalogued as rs149501332; called by muse, mutect2, varscan2
- EFS | c.1127C>T p.P376L | Missense Mutation (SNP) | VAF 51/352 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs754269591, COSV53732506, COSV99391675; called by muse, mutect2, varscan2
- EHBP1L1 | c.2315C>T p.A772V | Missense Mutation (SNP) | VAF 37/175 reads (21%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as rs375697464; called by muse, mutect2, varscan2
- EHMT1 | c.586G>A p.A196T | Missense Mutation (SNP) | VAF 33/137 reads (24%) | SIFT tolerated, low confidence (0.47); PolyPhen benign (0.001); catalogued as rs768398355; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- EHMT1 | c.1999G>A p.A667T | Missense Mutation (SNP) | VAF 12/284 reads (4%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.597); catalogued as COSV100604022; called by muse, mutect2
- EIF2S1 | c.800del p.G267Vfs*71 | Frame Shift Del (DEL) | VAF 44/260 reads (17%) | catalogued as COSV53606870; called by mutect2, pindel, varscan2
- EIF4G3 | c.421del p.T141Lfs*2 | Frame Shift Del (DEL) | VAF 14/43 reads (33%) | catalogued as rs1290746509; called by pindel, varscan2
- ELL | c.653G>A p.R218Q | Missense Mutation (SNP) | VAF 76/407 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.37); catalogued as rs200858673, COSV53213681; called by muse, mutect2, varscan2
- EMID1 | c.1144G>A p.E382K | Missense Mutation (SNP) | VAF 63/351 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.114); catalogued as rs200726069, COSV61829835; called by muse, mutect2, varscan2
- EML4 | c.1090C>T p.R364C | Missense Mutation (SNP) | VAF 25/126 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs772898650; called by muse, mutect2, varscan2
- ENDOG | c.446G>A p.R149H | Missense Mutation (SNP) | VAF 14/56 reads (25%) | SIFT tolerated (0.07); PolyPhen benign (0.365); catalogued as rs761051492; called by muse, mutect2, varscan2
- ENO4 | c.623del p.K208Rfs*32 (on ENST00000622726; = p.K207Rfs*32 on NM_001242699.2) | Frame Shift Del (DEL) | VAF 8/49 reads (16%) | catalogued as rs761717176; called by mutect2, varscan2
- EP300 | c.6691A>G p.M2231V | Missense Mutation (SNP) | VAF 103/426 reads (24%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.005); catalogued as rs780235974; called by muse, mutect2, varscan2
- EPB41L3 | c.97G>A p.V33M | Missense Mutation (SNP) | VAF 18/58 reads (31%) | SIFT tolerated (0.16); PolyPhen benign (0.001); catalogued as rs1397759498; called by muse, mutect2, varscan2
- EPHA2 | c.2826C>T p.D942= | Splice Region (SNP) | VAF 24/115 reads (21%) | catalogued as rs143828420; called by muse, mutect2, varscan2
- EPHB6 | c.2118G>T p.W706C | Missense Mutation (SNP) | VAF 219/1062 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV63893238, COSV99063846; called by muse, mutect2, varscan2
- EPHX3 | c.575G>A p.R192Q | Missense Mutation (SNP) | VAF 26/202 reads (13%) | SIFT deleterious (0.05); PolyPhen benign (0.298); catalogued as rs139340007; called by muse, mutect2, varscan2
- EPOR | c.1489G>A p.A497T | Missense Mutation (SNP) | VAF 88/436 reads (20%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as rs751352150; called by muse, mutect2, varscan2
- EPPIN | c.329G>A p.C110Y | Missense Mutation (SNP) | VAF 20/156 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100323040; called by muse, mutect2, varscan2
- EPS15L1 | c.1288C>T p.R430W | Missense Mutation (SNP) | VAF 32/198 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as rs1297220753, COSV50167451; called by muse, mutect2, varscan2
- EQTN | c.881G>A p.R294Q | Missense Mutation (SNP) | VAF 20/113 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as rs368040874; called by muse, mutect2, varscan2
- ESRP1 | c.1535del p.N512Tfs*2 | Frame Shift Del (DEL) | VAF 26/133 reads (20%) | catalogued as rs775950025; called by mutect2, varscan2
- ESYT1 | c.2311del p.R771Vfs*7 | Frame Shift Del (DEL) | VAF 76/459 reads (17%) | catalogued as rs774883662; called by mutect2, pindel, varscan2
- ETV1 | c.414del p.T139Hfs*116 | Frame Shift Del (DEL) | VAF 14/87 reads (16%) | catalogued as COSV54136078; called by mutect2, pindel, varscan2
- ETV3 | c.1416del p.K473Sfs*4 | Frame Shift Del (DEL) | VAF 46/259 reads (18%) | catalogued as rs1346789939; called by mutect2, pindel, varscan2
- ETV5 | c.1445C>T p.P482L | Missense Mutation (SNP) | VAF 81/493 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1281944233; called by muse, mutect2, varscan2
- EVC2 | c.80dup p.R28Pfs*28 | Frame Shift Ins (INS) | VAF 4/34 reads (12%) | catalogued as rs1383803030; called by pindel, varscan2
- EXOC6 | c.1543G>A p.D515N | Missense Mutation (SNP) | VAF 12/72 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.863); catalogued as rs1214118234, COSV53319222, COSV53332686; called by muse, mutect2, varscan2
- EXOSC7 | c.332G>A p.R111Q | Missense Mutation (SNP) | VAF 79/214 reads (37%) | SIFT tolerated (0.16); PolyPhen benign (0.043); catalogued as rs773101876, COSV55556058; called by muse, mutect2, varscan2
- F10 | c.1334G>A p.R445H | Missense Mutation (SNP) | VAF 46/264 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs1566922876, COSV100979380; called by muse, mutect2, varscan2
- FAM155A | c.355G>A p.A119T | Missense Mutation (SNP) | VAF 46/193 reads (24%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0.005); catalogued as rs1450168586; called by muse, mutect2, varscan2
- FAM163B | c.265G>A p.A89T | Missense Mutation (SNP) | VAF 68/525 reads (13%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs774432420, COSV104417532; called by muse, mutect2, varscan2
- FAM187B | c.713C>T p.S238F | Missense Mutation (SNP) | VAF 27/162 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV61200859; called by muse, mutect2, varscan2
- FAM83B | c.811G>A p.E271K | Missense Mutation (SNP) | VAF 29/191 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1209803420; called by muse, mutect2, varscan2
- FASN | c.6602C>T p.A2201V | Missense Mutation (SNP) | VAF 322/767 reads (42%) | SIFT tolerated (0.18); PolyPhen benign (0.055); catalogued as rs1339326274; called by muse, mutect2, varscan2
- FASTKD3 | c.428del p.K143Rfs*36 | Frame Shift Del (DEL) | VAF 78/402 reads (19%) | catalogued as rs773607911, COSV52947201; called by mutect2, varscan2
- FAT1 | c.10889A>G p.H3630R | Missense Mutation (SNP) | VAF 133/707 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.193); catalogued as rs372958192; called by muse, mutect2, varscan2
- FBN3 | c.2259del p.G754Afs*23 | Frame Shift Del (DEL) | VAF 65/371 reads (18%) | catalogued as COSV54456788; called by mutect2, pindel, varscan2
- FBXW10 | c.872-5T>C | Splice Region (SNP) | VAF 68/474 reads (14%) | catalogued as rs756073865, COSV100111142, COSV57321401; called by muse, mutect2, varscan2
- FER1L6 | c.4432G>A p.E1478K | Missense Mutation (SNP) | VAF 29/140 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.957); catalogued as rs746744523, COSV67548142; called by muse, mutect2, varscan2
- FGD6 | c.4044A>C p.K1348N | Missense Mutation (SNP) | VAF 9/62 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV59691862; called by muse, mutect2, varscan2
- FGD6 | c.2069C>T p.A690V | Missense Mutation (SNP) | VAF 48/300 reads (16%) | SIFT tolerated (0.19); PolyPhen benign (0.439); catalogued as rs1254793587; called by muse, mutect2, varscan2
- FGFBP1 | c.78del p.V27* | Frame Shift Del (DEL) | VAF 56/256 reads (22%) | catalogued as rs144178676; called by mutect2, varscan2
- FHOD1 | c.2066G>A p.R689Q | Missense Mutation (SNP) | VAF 37/174 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.33); catalogued as rs370261438; called by muse, mutect2, varscan2
- FHOD3 | c.1005del p.S336Vfs*138 | Frame Shift Del (DEL) | VAF 19/144 reads (13%) | catalogued as rs777980924; called by mutect2, pindel, varscan2
- FICD | c.919G>A p.G307S | Missense Mutation (SNP) | VAF 95/486 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs150651188; called by muse, mutect2, varscan2
- FKBP8 | c.8C>T p.S3L | Missense Mutation (SNP) | VAF 58/291 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.953); catalogued as rs543806511; called by muse, mutect2, varscan2
- FKRP | c.37G>A p.A13T | Missense Mutation (SNP) | VAF 38/208 reads (18%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.894); catalogued as rs768376273, CM157209; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FLG | c.4700G>A p.R1567Q | Missense Mutation (SNP) | VAF 151/854 reads (18%) | SIFT tolerated (0.59); PolyPhen benign (0.005); catalogued as rs372914204, COSV100911731; called by muse, varscan2
- FLRT2 | c.1507G>A p.A503T | Missense Mutation (SNP) | VAF 43/346 reads (12%) | SIFT tolerated (0.64); PolyPhen benign (0); catalogued as rs149005998; called by muse, mutect2, varscan2
- FNBP1L | c.219del p.F73Lfs*7 | Frame Shift Del (DEL) | VAF 9/88 reads (10%) | catalogued as rs748660862; called by mutect2, pindel
- FOXP1 | c.995C>T p.A332V | Missense Mutation (SNP) | VAF 44/377 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.139); catalogued as rs971116457, COSV59558070; called by muse, mutect2, varscan2
- FOXP2 | c.1352C>T p.T451M | Missense Mutation (SNP) | VAF 117/704 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.985); catalogued as rs199776572; called by muse, mutect2, varscan2
- FRMPD3 | c.4882C>T p.R1628W | Missense Mutation (SNP) | VAF 103/254 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.349); catalogued as rs761487802; called by muse, mutect2, varscan2
- FTHL17 | c.470G>T p.R157L | Missense Mutation (SNP) | VAF 97/237 reads (41%) | SIFT deleterious (0.03); PolyPhen benign (0.175); catalogued as COSV63266410; called by muse, mutect2, varscan2
- FXR1 | c.371del p.N124Ifs*14 | Frame Shift Del (DEL) | VAF 16/90 reads (18%) | catalogued as rs756304971; called by mutect2, varscan2
- GABBR1 | c.1811T>C p.V604A | Missense Mutation (SNP) | VAF 18/232 reads (8%) | SIFT tolerated (0.12); PolyPhen benign (0.24); catalogued as COSV100589530; called by muse, mutect2
- GABRA5 | c.955G>A p.A319T | Missense Mutation (SNP) | VAF 53/396 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.918); catalogued as rs1175270301; called by muse, mutect2, varscan2
- GABRB1 | c.424C>T p.R142* | Nonsense Mutation (SNP) | VAF 60/324 reads (19%) | catalogued as COSV54975145; called by muse, mutect2, varscan2
- GAL3ST2 | c.979G>A p.A327T | Missense Mutation (SNP) | VAF 11/46 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.021); catalogued as COSV51950180; called by muse, varscan2
- GALR2 | c.455T>C p.L152P | Missense Mutation (SNP) | VAF 50/274 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs61741641; called by muse, mutect2, varscan2
- GATA6 | c.1316G>A p.R439Q | Missense Mutation (SNP) | VAF 99/526 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.441); catalogued as rs1462417792; called by muse, mutect2, varscan2
- GATAD2A | c.155C>T p.P52L | Missense Mutation (SNP) | VAF 85/520 reads (16%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as rs773127387; called by muse, mutect2, varscan2
- GCNT7 | c.826C>T p.R276W | Missense Mutation (SNP) | VAF 53/292 reads (18%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.882); catalogued as rs1232407021, COSV99196521; called by muse, mutect2, varscan2
- GDF1 | c.206G>A p.R69Q | Missense Mutation (SNP) | VAF 67/266 reads (25%) | SIFT tolerated (0.09); PolyPhen benign (0.026); catalogued as rs775390513; called by muse, mutect2, varscan2
- GDF7 | c.797C>T p.A266V | Missense Mutation (SNP) | VAF 88/219 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs867444165, COSV55347273; called by muse, mutect2, varscan2
- GEMIN6 | c.158G>A p.G53D | Missense Mutation (SNP) | VAF 15/68 reads (22%) | SIFT tolerated (0.2); PolyPhen benign (0.029); catalogued as rs1477686147; called by muse, mutect2, varscan2
- GGH | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 10/77 reads (13%) | SIFT tolerated (0.21); PolyPhen benign (0.346); catalogued as COSV52649521; called by muse, mutect2, varscan2
- GIGYF1 | c.1787C>T p.P596L | Missense Mutation (SNP) | VAF 60/348 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as rs769494936, COSV99309787; called by muse, varscan2
- GIGYF1 | c.323G>C p.G108A | Missense Mutation (SNP) | VAF 105/282 reads (37%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as rs747805291, COSV51940895; called by mutect2, varscan2
- GJC1 | c.389C>T p.T130M | Missense Mutation (SNP) | VAF 33/211 reads (16%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.535); catalogued as rs753057256, COSV57911321; called by muse, mutect2, varscan2
- GLI1 | c.821del p.G274Afs*6 | Frame Shift Del (DEL) | VAF 47/197 reads (24%) | catalogued as rs759448855, COSV99954330; called by mutect2, varscan2
- GLIS2 | c.1373T>C p.M458T | Missense Mutation (SNP) | VAF 98/718 reads (14%) | SIFT tolerated, low confidence (0.57); PolyPhen benign (0); catalogued as rs748007729; called by muse, mutect2, varscan2
- GLYR1 | c.1140dup p.R381Afs*15 | Frame Shift Ins (INS) | VAF 48/142 reads (34%) | catalogued as rs749150409; called by mutect2, varscan2
- GNAS | c.1753A>T p.T585S | Missense Mutation (SNP) | VAF 202/850 reads (24%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.007); catalogued as rs1434670734; called by muse, mutect2, varscan2
- GNAS | c.1117C>T p.R373C | Missense Mutation (SNP) | VAF 60/390 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs759578554, COSV55682161; called by muse, mutect2, varscan2
- GNAZ | c.612dup p.Q205Afs*35 | Frame Shift Ins (INS) | VAF 56/304 reads (18%) | catalogued as rs752075537; called by mutect2, varscan2
- GNL3 | c.1541A>G p.E514G | Missense Mutation (SNP) | VAF 24/159 reads (15%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as COSV56478484; called by muse, mutect2, varscan2
- GNS | c.1616G>A p.R539H | Missense Mutation (SNP) | VAF 65/409 reads (16%) | SIFT tolerated, low confidence (0.88); PolyPhen benign (0); catalogued as rs766615352; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- GPR176 | c.1160A>G p.E387G | Missense Mutation (SNP) | VAF 18/515 reads (3%) | SIFT deleterious (0); PolyPhen possibly damaging (0.655); catalogued as COSV54446952; called by muse, mutect2
- GPR182 | c.851A>G p.H284R | Missense Mutation (SNP) | VAF 74/435 reads (17%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.494); catalogued as COSV55626227; called by muse, mutect2, varscan2
- GPR35 | c.220C>T p.P74S | Missense Mutation (SNP) | VAF 47/274 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1224652856; called by muse, mutect2, varscan2
- GPR45 | c.679G>A p.V227M | Missense Mutation (SNP) | VAF 79/380 reads (21%) | SIFT tolerated (0.28); PolyPhen benign (0.183); catalogued as COSV51524999; called by muse, mutect2, varscan2
- GRIA1 | c.954del p.N319Mfs*31 | Frame Shift Del (DEL) | VAF 20/158 reads (13%) | catalogued as COSV53614709; called by mutect2, pindel, varscan2
- GRIA1 | c.1081C>T p.R361W | Missense Mutation (SNP) | VAF 30/191 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53605708; called by muse, mutect2, varscan2
- GRIA2 | c.2086C>T p.R696W | Missense Mutation (SNP) | VAF 75/374 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs754294298, COSV52396106; called by muse, mutect2, varscan2
- GRIFIN | c.358C>T p.R120C | Missense Mutation (SNP) | VAF 60/297 reads (20%) | SIFT tolerated (0.33); PolyPhen benign (0.014); catalogued as rs766790997; called by muse, mutect2, varscan2
- GRIK3 | c.1483G>T p.D495Y | Missense Mutation (SNP) | VAF 181/885 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as COSV66139322, COSV66145636; called by muse, mutect2, varscan2
- GRIN3B | c.1920del p.T641Rfs*6 | Frame Shift Del (DEL) | VAF 76/448 reads (17%) | catalogued as rs1265788787; called by mutect2, pindel, varscan2
- GRK6 | c.121C>A p.Q41K | Missense Mutation (SNP) | VAF 24/302 reads (8%) | SIFT tolerated (0.25); PolyPhen benign (0.028); catalogued as COSV100586811; called by muse, mutect2
- GRM3 | c.1388T>C p.M463T | Missense Mutation (SNP) | VAF 51/381 reads (13%) | SIFT tolerated (0.39); PolyPhen benign (0.059); catalogued as COSV64470076; called by muse, mutect2, varscan2
- GRM4 | c.2123C>T p.S708L | Missense Mutation (SNP) | VAF 103/483 reads (21%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.506); catalogued as rs751971588; called by muse, mutect2, varscan2
- GRM8 | c.2158del p.H720Tfs*12 | Frame Shift Del (DEL) | VAF 51/294 reads (17%) | catalogued as COSV58842099; called by mutect2, pindel, varscan2
- GTDC1 | c.220G>A p.A74T | Missense Mutation (SNP) | VAF 33/168 reads (20%) | SIFT tolerated (0.18); PolyPhen benign (0.043); catalogued as COSV99600543; called by muse, mutect2, varscan2
- GTF2B | c.395G>A p.R132Q | Missense Mutation (SNP) | VAF 29/150 reads (19%) | SIFT tolerated (0.35); PolyPhen benign (0.015); catalogued as rs144944840; called by muse, mutect2, varscan2
- GTF3C1 | c.5541del p.E1848Rfs*33 | Frame Shift Del (DEL) | VAF 25/138 reads (18%) | catalogued as rs763161381; called by mutect2, pindel, varscan2
- GTPBP1 | c.1346G>A p.R449H | Missense Mutation (SNP) | VAF 18/358 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53284066; called by muse, mutect2
- H4C13 | c.236G>A p.R79H | Missense Mutation (SNP) | VAF 48/382 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.936); catalogued as rs775836737; called by muse, mutect2, varscan2
- HAAO | c.553G>A p.A185T | Missense Mutation (SNP) | VAF 41/225 reads (18%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as rs543681141; called by muse, mutect2, varscan2
- HAAO | c.193C>T p.R65* | Nonsense Mutation (SNP) | VAF 33/234 reads (14%) | catalogued as rs773874847; called by muse, mutect2, varscan2
- HAL | c.1576G>A p.A526T | Missense Mutation (SNP) | VAF 48/739 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.889); catalogued as rs772267203; called by muse, mutect2
- HDGFL1 | c.688G>A p.A230T | Missense Mutation (SNP) | VAF 11/115 reads (10%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.897); catalogued as COSV57751109; called by muse, mutect2
- HECTD4 | c.9644C>T p.S3215L | Missense Mutation (SNP) | VAF 51/301 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.207); catalogued as rs1167421431; called by muse, mutect2, varscan2
- HECW1 | c.886C>T p.R296C | Missense Mutation (SNP) | VAF 37/207 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1335374674, COSV67836832, COSV67837728; called by muse, mutect2, varscan2
- HELQ | c.2630A>G p.D877G | Missense Mutation (SNP) | VAF 26/106 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.271); catalogued as rs979658363; called by muse, mutect2, varscan2
- HERC1 | c.4273C>T p.R1425* | Nonsense Mutation (SNP) | VAF 46/408 reads (11%) | catalogued as COSV101497108; called by muse, mutect2, varscan2
- HERC2 | c.7649C>T p.T2550M | Missense Mutation (SNP) | VAF 22/133 reads (17%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as rs748935454; called by muse, mutect2, varscan2
- HERC2 | c.1083+1G>A p.X361_splice | Splice Site (SNP) | VAF 13/51 reads (25%) | catalogued as rs757232123, COSV99870328; called by muse, mutect2, varscan2
- HIC1 | c.704G>A p.R235H (on ENST00000322941 / NM_001098202.1; = p.R216H on NM_006497.4) | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as rs968501586; called by muse, varscan2
- HIP1R | c.2425C>T p.R809C | Missense Mutation (SNP) | VAF 29/209 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs752926145, COSV53444615; called by muse, mutect2, varscan2
- HK2 | c.1246G>A p.V416I | Missense Mutation (SNP) | VAF 186/943 reads (20%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.502); catalogued as rs1450833900; called by muse, mutect2, varscan2
- HNRNPL | c.1010dup p.P338Tfs*56 | Frame Shift Ins (INS) | VAF 18/82 reads (22%) | catalogued as rs767148651; called by mutect2, varscan2
- HNRNPM | c.1252C>T p.R418C | Missense Mutation (SNP) | VAF 95/373 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.948); catalogued as rs1394060360, COSV99725266; called by muse, mutect2, varscan2
- HNRNPUL1 | c.1795C>T p.R599C | Missense Mutation (SNP) | VAF 32/202 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs1456226114, COSV54559773; called by muse, mutect2, varscan2
- HSPA2 | c.535G>A p.A179T | Missense Mutation (SNP) | VAF 109/568 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.977); catalogued as COSV55970942; called by muse, mutect2, varscan2
- HTR1A | c.1229C>T p.A410V | Missense Mutation (SNP) | VAF 120/641 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV60503115; called by muse, mutect2, varscan2
- HTRA2 | c.346dup p.A116Gfs*22 | Frame Shift Ins (INS) | VAF 28/168 reads (17%) | catalogued as rs779457274; called by mutect2, varscan2
- HUNK | c.1337G>T p.G446V | Missense Mutation (SNP) | VAF 31/151 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.255); catalogued as COSV99528609; called by muse, mutect2, varscan2
- HUWE1 | c.6484C>T p.R2162W | Missense Mutation (SNP) | VAF 125/327 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV53333602, COSV53361602; called by muse, mutect2, varscan2
- HYAL2 | c.1135C>T p.R379C | Missense Mutation (SNP) | VAF 26/509 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as rs1472320415, COSV63306114; called by muse, mutect2
- IARS1 | c.2428C>T p.R810* | Nonsense Mutation (SNP) | VAF 18/111 reads (16%) | catalogued as rs373980273; called by muse, mutect2, varscan2
- ICA1 | c.587C>T p.T196I | Missense Mutation (SNP) | VAF 24/134 reads (18%) | SIFT tolerated (0.45); PolyPhen benign (0.047); catalogued as rs952572650; called by muse, mutect2, varscan2
- ICAM5 | c.2150G>T p.R717L | Missense Mutation (SNP) | VAF 47/229 reads (21%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.997); catalogued as rs1279990973, COSV55747673; called by mutect2, varscan2
- IFNL2 | c.503del p.K168Rfs*23 | Frame Shift Del (DEL) | VAF 36/160 reads (23%) | catalogued as rs1225989269; called by mutect2, varscan2
- IFT81 | c.1313G>A p.R438H | Missense Mutation (SNP) | VAF 15/74 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.239); catalogued as rs748765767, COSV54365631; called by muse, mutect2, varscan2
- IGF1R | c.2101G>A p.A701T | Missense Mutation (SNP) | VAF 93/740 reads (13%) | SIFT tolerated (0.14); PolyPhen benign (0.029); catalogued as rs201631492, COSV51336623; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- IGF2 | c.182T>C p.M61T (on ENST00000434045 / NM_001127598.3; = p.M5T on NM_000612.6) | Missense Mutation (SNP) | VAF 19/154 reads (12%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as rs757907236; called by muse, mutect2, varscan2
- IGKV1-5 | c.304C>T p.P102S | Missense Mutation (SNP) | VAF 79/464 reads (17%) | SIFT tolerated (0.17); PolyPhen benign (0.176); catalogued as rs546309985; called by muse, mutect2, varscan2
- IGLL5 | c.575G>A p.S192N | Missense Mutation (SNP) | VAF 112/1086 reads (10%) | SIFT tolerated, low confidence (0.5); PolyPhen benign (0.122); catalogued as rs11558639; called by muse, mutect2, varscan2
- IGLV1-36 | c.145G>A p.G49R | Missense Mutation (SNP) | VAF 82/384 reads (21%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0.168); catalogued as rs766040875; called by muse, mutect2, varscan2
- IGLV3-16 | c.147del p.K49Nfs*17 | Frame Shift Del (DEL) | VAF 79/502 reads (16%) | catalogued as rs746629447; called by mutect2, varscan2
- IGSF9B | c.2371C>T p.R791* | Nonsense Mutation (SNP) | VAF 26/156 reads (17%) | catalogued as rs1251265858, COSV100318613; called by muse, varscan2
- IGSF9B | c.842G>A p.R281H | Missense Mutation (SNP) | VAF 79/329 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.833); catalogued as rs1412418017, COSV58072623; called by muse, mutect2, varscan2
- IL11RA | c.1123C>A p.L375I | Missense Mutation (SNP) | VAF 227/1173 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.036); catalogued as COSV52405048; called by muse, mutect2, varscan2
- IL17RC | c.1735+1dup | Frame Shift Ins (INS) | VAF 18/108 reads (17%) | catalogued as rs1341716326; called by mutect2, pindel, varscan2
- IL1RL1 | c.1198T>G p.F400V | Missense Mutation (SNP) | VAF 37/238 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52117803; called by muse, mutect2, varscan2
- IL22RA2 | c.410C>T p.A137V | Missense Mutation (SNP) | VAF 31/193 reads (16%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.699); catalogued as rs141572567; called by muse, mutect2, varscan2
- IL2RG | c.167C>T p.P56L | Missense Mutation (SNP) | VAF 26/183 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.551); catalogued as rs774569887; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ILF3 | c.113C>T p.T38M | Missense Mutation (SNP) | VAF 26/156 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs1274954871; called by muse, varscan2
- IMP4 | c.337C>T p.R113* | Nonsense Mutation (SNP) | VAF 149/659 reads (23%) | catalogued as rs1270307399; called by muse, mutect2, varscan2
- INO80 | c.2309G>A p.R770Q | Missense Mutation (SNP) | VAF 21/99 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs1466180067, COSV62739938; called by muse, mutect2, varscan2
- INO80D | c.2158C>T p.R720C | Missense Mutation (SNP) | VAF 52/530 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs776202202, COSV104434934, COSV68960441; called by muse, mutect2
- INPP4A | c.1543C>T p.R515* | Nonsense Mutation (SNP) | VAF 40/216 reads (19%) | catalogued as rs1227700629, COSV50862240; called by muse, mutect2, varscan2
- INPP5A | c.1028G>A p.R343Q | Missense Mutation (SNP) | VAF 60/262 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.778); catalogued as COSV100704510, COSV61246579; called by muse, mutect2, varscan2
- INTS1 | c.3944G>A p.R1315H | Missense Mutation (SNP) | VAF 29/298 reads (10%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as rs773714369; called by muse, varscan2
- INTS11 | c.166C>T p.R56C | Missense Mutation (SNP) | VAF 55/329 reads (17%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.892); catalogued as rs763651338; called by muse, mutect2, varscan2
- INVS | c.2207C>T p.A736V | Missense Mutation (SNP) | VAF 79/451 reads (18%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0); catalogued as rs111783825; called by muse, mutect2, varscan2
- IRF5 | c.941C>T p.T314M | Missense Mutation (SNP) | VAF 125/606 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1279982666; called by muse, mutect2, varscan2
- IRX3 | c.818C>T p.A273V | Missense Mutation (SNP) | VAF 35/430 reads (8%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as rs1200247563, COSV61668084; called by muse, mutect2
- IRX5 | c.311C>T p.A104V | Missense Mutation (SNP) | VAF 90/482 reads (19%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.534); catalogued as rs1255566733, COSV100315577; called by muse, mutect2, varscan2
- ISLR | c.904C>T p.P302S | Missense Mutation (SNP) | VAF 103/545 reads (19%) | SIFT tolerated (0.46); PolyPhen benign (0.02); catalogued as rs1302067558; called by muse, mutect2, varscan2
- ITGA10 | c.1331G>A p.R444H | Missense Mutation (SNP) | VAF 18/123 reads (15%) | SIFT tolerated (0.11); PolyPhen benign (0.336); catalogued as rs781994799, COSV65196843, COSV65199161; called by muse, mutect2, varscan2
- ITPA | c.253G>A p.G85S | Missense Mutation (SNP) | VAF 69/381 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1343080275; called by muse, mutect2, varscan2
- JAG1 | c.2048G>A p.R683H | Missense Mutation (SNP) | VAF 192/1036 reads (19%) | SIFT tolerated (0.51); PolyPhen benign (0.037); catalogued as rs200929472, COSV54753729; called by muse, mutect2, varscan2
- JAG2 | c.2273A>G p.N758S | Missense Mutation (SNP) | VAF 134/671 reads (20%) | SIFT tolerated (0.46); PolyPhen benign (0.047); catalogued as COSV59306963; called by muse, mutect2, varscan2
- JAKMIP3 | c.533C>T p.A178V | Missense Mutation (SNP) | VAF 110/642 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1165488740, COSV53819878; called by muse, mutect2, varscan2
- JARID2 | c.3325C>T p.R1109C | Missense Mutation (SNP) | VAF 30/323 reads (9%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.664); catalogued as COSV59189155; called by muse, mutect2
- JDP2 | c.374G>T p.R125L | Missense Mutation (SNP) | VAF 31/197 reads (16%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.65); catalogued as COSV99966752; called by muse, mutect2, varscan2
- KAT14 | c.2341C>T p.R781W | Missense Mutation (SNP) | VAF 12/92 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs542639313; called by muse, mutect2, varscan2
- KAT2B | c.796C>T p.R266* | Nonsense Mutation (SNP) | VAF 41/151 reads (27%) | catalogued as rs759821361; called by muse, mutect2, varscan2
- KATNAL2 | c.1165C>T p.R389C (on ENST00000356157 / NM_001353899.1; = p.R317C on NM_031303.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 22/164 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.953); catalogued as rs372464270; called by muse, mutect2, varscan2
- KATNBL1 | c.433del p.S145Lfs*19 | Frame Shift Del (DEL) | VAF 6/60 reads (10%) | catalogued as rs1206265094; called by mutect2, pindel
- KATNIP | c.4234G>A p.D1412N | Missense Mutation (SNP) | VAF 19/109 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1306182406; called by muse, mutect2, varscan2
- KBTBD4 | c.982G>A p.G328R | Missense Mutation (SNP) | VAF 73/513 reads (14%) | SIFT tolerated (0.19); PolyPhen benign (0.166); catalogued as rs1036617814, COSV100442829; called by muse, mutect2, varscan2
- KBTBD7 | c.275C>T p.A92V | Missense Mutation (SNP) | VAF 87/753 reads (12%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.869); catalogued as COSV65266559; called by muse, mutect2, varscan2
- KCNA1 | c.77G>A p.R26Q | Missense Mutation (SNP) | VAF 103/862 reads (12%) | SIFT tolerated, low confidence (0.5); PolyPhen benign (0); catalogued as COSV66839049; called by muse, mutect2, varscan2
- KCNA4 | c.1286del p.G429Vfs*53 | Frame Shift Del (DEL) | VAF 94/463 reads (20%) | catalogued as rs1258313537; called by mutect2, varscan2
- KCNA5 | c.1704del p.T569Pfs*15 | Frame Shift Del (DEL) | VAF 106/514 reads (21%) | catalogued as rs1565466174, COSV99363705; called by mutect2, varscan2
- KCNB1 | c.1748G>A p.R583Q | Missense Mutation (SNP) | VAF 69/340 reads (20%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.814); catalogued as rs755481445, COSV100870504; called by muse, mutect2, varscan2
- KCNB2 | c.435del p.E146Nfs*3 | Frame Shift Del (DEL) | VAF 57/260 reads (22%) | catalogued as rs752059864; called by mutect2, varscan2
- KCNC1 | c.946G>A p.V316M | Missense Mutation (SNP) | VAF 121/612 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1238808659, COSV56393236; called by muse, mutect2, varscan2
- KCNG1 | c.430G>A p.A144T | Missense Mutation (SNP) | VAF 60/622 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as rs1463537606, COSV100857223; called by muse, mutect2
- KCNH1 | c.2078G>A p.R693Q (on ENST00000271751 / NM_172362.3; = p.R666Q on NM_002238.4) | Missense Mutation (SNP) | VAF 20/201 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.315); catalogued as COSV55111110; called by muse, mutect2, varscan2
- KCNK13 | c.1171dup p.V391Gfs*67 | Frame Shift Ins (INS) | VAF 30/169 reads (18%) | catalogued as rs766469179; called by mutect2, varscan2
- KCNMA1 | c.1096C>T p.R366C | Missense Mutation (SNP) | VAF 75/454 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs1453880868, COSV54254333; called by muse, varscan2
- KCNQ4 | c.1052G>A p.R351H | Missense Mutation (SNP) | VAF 76/424 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs764064113, COSV100714338; called by muse, mutect2, varscan2
- KCNS1 | c.1069C>T p.R357C | Missense Mutation (SNP) | VAF 54/349 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60259861; called by muse, mutect2, varscan2
- KCNS1 | c.653C>T p.P218L | Missense Mutation (SNP) | VAF 42/205 reads (20%) | SIFT tolerated (0.18); PolyPhen benign (0.03); catalogued as rs1340367554; called by muse, mutect2, varscan2
- KCNS3 | c.610G>A p.V204I | Missense Mutation (SNP) | VAF 67/432 reads (16%) | SIFT tolerated (0.85); PolyPhen benign (0); catalogued as rs144701569, COSV58407598; called by muse, mutect2, varscan2
- KDM2B | c.3017G>A p.R1006Q | Missense Mutation (SNP) | VAF 86/375 reads (23%) | SIFT tolerated (0.39); PolyPhen benign (0.009); catalogued as rs782721641, COSV65640411; called by muse, mutect2, varscan2
- KDM3A | c.1664G>A p.R555H | Missense Mutation (SNP) | VAF 26/297 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.869); catalogued as rs761075398, COSV57223698; called by muse, mutect2
- KDM5C | c.3441C>T p.I1147= | Splice Region (SNP) | VAF 24/374 reads (6%) | catalogued as rs45442400, COSV100949280; ClinVar: benign / likely benign; called by muse, mutect2
- KIAA0100 | c.151del p.W51Gfs*77 | Frame Shift Del (DEL) | VAF 20/123 reads (16%) | catalogued as rs1339576763; called by mutect2, pindel, varscan2
- KIAA0753 | c.2498C>T p.T833M | Missense Mutation (SNP) | VAF 19/156 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.242); catalogued as rs751067090, COSV63818664; called by muse, mutect2, varscan2
- KIAA0930 | c.1189C>T p.R397W (on ENST00000336156 / NM_001009880.2; = p.R402W on NM_015264.2) | Missense Mutation (SNP) | VAF 31/172 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1486823130; called by muse, mutect2, varscan2
- KIAA1522 | c.587G>A p.R196H (on ENST00000373480 / NM_001198972.2; = p.R255H on NM_020888.3) | Missense Mutation (SNP) | VAF 32/320 reads (10%) | SIFT tolerated (0.6); PolyPhen benign (0.005); catalogued as rs778742442, COSV53867384; called by muse, mutect2
- KIF1A | c.3863C>T p.P1288L (on ENST00000320389 / NM_001379639.1; = p.P1280L on NM_004321.8 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 44/248 reads (18%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.979); catalogued as rs766841187, COSV57483722; called by muse, mutect2, varscan2
- KIF25 | c.136G>A p.V46M | Missense Mutation (SNP) | VAF 20/155 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.823); catalogued as COSV63028985; called by muse, mutect2, varscan2
- KIF26A | c.492del p.S165Afs*43 | Frame Shift Del (DEL) | VAF 55/343 reads (16%) | catalogued as rs1421505927; called by mutect2, pindel, varscan2
- KIF26A | c.2098G>A p.A700T | Missense Mutation (SNP) | VAF 26/219 reads (12%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.757); catalogued as rs1232588034; called by muse, mutect2, varscan2
- KIF26B | c.3199del p.R1067Gfs*65 | Frame Shift Del (DEL) | VAF 101/558 reads (18%) | catalogued as COSV63639593; called by mutect2, pindel, varscan2
- KIF26B | c.5051G>A p.R1684Q | Missense Mutation (SNP) | VAF 41/379 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1015989309; called by muse, mutect2, varscan2
- KIF3B | c.1138C>T p.R380* | Nonsense Mutation (SNP) | VAF 30/178 reads (17%) | catalogued as COSV100996276; called by muse, mutect2, varscan2
- KIF6 | c.1452dup p.E485Rfs*16 | Frame Shift Ins (INS) | VAF 19/150 reads (13%) | catalogued as rs755810135; called by mutect2, varscan2
- KIFC1 | c.721C>T p.R241W | Missense Mutation (SNP) | VAF 34/197 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.018); catalogued as rs749380644; called by muse, mutect2, varscan2
- KIFC1 | c.1315C>T p.R439W | Missense Mutation (SNP) | VAF 47/213 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1008439703, COSV65737822; called by muse, mutect2, varscan2
- KIRREL1 | c.1009del p.L337Sfs*14 | Frame Shift Del (DEL) | VAF 6/42 reads (14%) | catalogued as rs754171400, COSV63285253; called by mutect2, varscan2
- KIRREL3 | c.1196G>T p.R399L | Missense Mutation (SNP) | VAF 30/213 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.5); catalogued as rs375260772; called by muse, mutect2, varscan2
- KLF13 | c.781G>A p.G261S | Missense Mutation (SNP) | VAF 49/182 reads (27%) | SIFT tolerated (0.11); PolyPhen benign (0.033); catalogued as rs766830250, COSV56147544; called by muse, mutect2, varscan2
- KLF14 | c.359G>A p.C120Y | Missense Mutation (SNP) | VAF 16/67 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.277); catalogued as rs1187546989; called by muse, mutect2, varscan2
- KLHL17 | c.1042+2T>C p.X348_splice | Splice Site (SNP) | VAF 36/173 reads (21%) | catalogued as rs1166943032; called by muse, mutect2, varscan2
- KLHL17 | c.1840C>T p.R614C | Missense Mutation (SNP) | VAF 120/662 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.451); catalogued as COSV58530694; called by muse, mutect2, varscan2
- KLKB1 | c.1169G>A p.R390H | Missense Mutation (SNP) | VAF 147/749 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs369481447; called by muse, mutect2, varscan2
- KMT2A | c.2632C>T p.R878W | Missense Mutation (SNP) | VAF 46/209 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as rs1555036661, COSV63283057; called by muse, mutect2, varscan2
- KMT2A | c.9337A>G p.S3113G | Missense Mutation (SNP) | VAF 14/365 reads (4%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0); catalogued as rs782745599; called by muse, mutect2
- KMT2B | c.2291C>T p.P764L | Missense Mutation (SNP) | VAF 89/377 reads (24%) | SIFT tolerated, low confidence (0.55); PolyPhen benign (0.027); catalogued as rs144673174; called by muse, mutect2, varscan2
- KMT2D | c.4454del p.P1485Lfs*21 | Frame Shift Del (DEL) | VAF 31/222 reads (14%) | catalogued as CD146905; called by mutect2, pindel, varscan2
- KMT5C | c.592G>A p.A198T | Missense Mutation (SNP) | VAF 65/257 reads (25%) | SIFT tolerated (1); PolyPhen benign (0.014); catalogued as rs1179391138, COSV55319315; called by muse, mutect2, varscan2
- KNSTRN | c.316C>T p.R106W | Missense Mutation (SNP) | VAF 18/101 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1291020860; called by muse, mutect2, varscan2
- KRBA1 | c.3085del p.A1029Rfs*53 | Frame Shift Del (DEL) | VAF 28/198 reads (14%) | catalogued as rs1008481842, COSV99753011; called by mutect2, pindel, varscan2
- KRIT1 | c.1205A>G p.N402S | Missense Mutation (SNP) | VAF 21/199 reads (11%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.952); catalogued as rs1300250974, CD022708; called by muse, mutect2
- KRT3 | c.1735G>A p.G579S | Missense Mutation (SNP) | VAF 66/635 reads (10%) | SIFT tolerated (0.55); PolyPhen benign (0.022); catalogued as rs772879943, COSV58814764; called by muse, mutect2, varscan2
- KRT35 | c.1331G>A p.R444H | Missense Mutation (SNP) | VAF 18/125 reads (14%) | SIFT tolerated (0.36); PolyPhen benign (0.001); catalogued as rs769662906, COSV55843983; called by muse, mutect2
- KRT73 | c.1294G>A p.A432T | Missense Mutation (SNP) | VAF 87/520 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.668); catalogued as COSV59838123; called by muse, mutect2, varscan2
- KRTAP10-5 | c.136T>C p.C46R | Missense Mutation (SNP) | VAF 160/884 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as rs202206811; called by mutect2, varscan2
- KRTAP26-1 | c.431G>A p.R144H | Missense Mutation (SNP) | VAF 44/290 reads (15%) | SIFT tolerated (0.18); PolyPhen benign (0.119); catalogued as rs767826058, COSV62128671; called by muse, mutect2, varscan2
- KSR1 | c.1970C>T p.P657L (on ENST00000644974 / NM_001367810.1; = p.P542L on NM_014238.2) | Missense Mutation (SNP) | VAF 27/326 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.958); catalogued as rs752914455; called by muse, mutect2
- LAMA5 | c.3804del p.T1269Pfs*86 | Frame Shift Del (DEL) | VAF 61/336 reads (18%) | catalogued as rs1305810246; called by mutect2, pindel, varscan2
- LAMA5 | c.593G>A p.R198Q | Missense Mutation (SNP) | VAF 36/280 reads (13%) | SIFT tolerated (0.13); PolyPhen benign (0.246); catalogued as rs373237521; called by muse, mutect2
- LAMC1 | c.2393G>A p.G798D | Missense Mutation (SNP) | VAF 26/117 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs780749617; called by muse, mutect2, varscan2
- LAMC2 | c.155G>A p.R52H | Missense Mutation (SNP) | VAF 79/350 reads (23%) | SIFT tolerated (0.56); PolyPhen possibly damaging (0.79); catalogued as COSV51454717, COSV51459492; called by muse, mutect2, varscan2
- LGALS8 | c.697C>T p.R233C (on ENST00000341872; = p.R275C on NM_006499.4) | Missense Mutation (SNP) | VAF 15/121 reads (12%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.538); catalogued as rs769554222; called by muse, mutect2, varscan2
- LHX1 | c.1194del p.E399Kfs*2 | Frame Shift Del (DEL) | VAF 41/217 reads (19%) | catalogued as rs775423572; called by mutect2, pindel, varscan2
- LIG1 | c.361C>T p.R121C | Missense Mutation (SNP) | VAF 13/65 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs573726688; called by muse, mutect2, varscan2
- LILRA1 | c.932G>A p.S311N | Missense Mutation (SNP) | VAF 35/688 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1476376639, COSV52181902; called by muse, mutect2
- LINS1 | c.1766G>A p.R589Q | Missense Mutation (SNP) | VAF 25/122 reads (20%) | SIFT tolerated (0.31); PolyPhen benign (0.001); catalogued as rs1164714549; called by muse, mutect2, varscan2
- LIPT1 | c.368del p.K123Sfs*8 | Frame Shift Del (DEL) | VAF 28/154 reads (18%) | catalogued as rs780042765; called by mutect2, varscan2
- LMF2 | c.805G>A p.G269S | Missense Mutation (SNP) | VAF 75/303 reads (25%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.991); catalogued as rs750604911, COSV99327877; called by muse, mutect2, varscan2
- LMNB2 | c.1022C>T p.A341V | Missense Mutation (SNP) | VAF 154/733 reads (21%) | SIFT tolerated (0.12); PolyPhen benign (0.015); catalogued as COSV57590588; called by muse, mutect2, varscan2
- LMNB2 | c.541C>T p.R181W | Missense Mutation (SNP) | VAF 191/914 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.888); catalogued as rs1204917895; called by muse, mutect2, varscan2
- LNPEP | c.2017T>G p.L673V | Missense Mutation (SNP) | VAF 19/92 reads (21%) | SIFT tolerated (0.06); PolyPhen benign (0.08); catalogued as COSV51477912; called by muse, varscan2
- LPA | c.5469dup p.C1824Vfs*72 | Frame Shift Ins (INS) | VAF 57/326 reads (17%) | catalogued as rs752960449; called by mutect2, pindel, varscan2
- LRCH4 | c.1739G>A p.R580H | Missense Mutation (SNP) | VAF 69/303 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs750336915; called by muse, mutect2, varscan2
- LRP12 | c.1351del p.C451Afs*37 | Frame Shift Del (DEL) | VAF 38/234 reads (16%) | catalogued as rs35928649; called by mutect2, varscan2
- LRP5 | c.2134G>A p.V712M | Missense Mutation (SNP) | VAF 79/336 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as rs765239493, COSV53712978; called by muse, varscan2
- LRRC37B | c.2242+1G>A p.X748_splice | Splice Site (SNP) | VAF 19/101 reads (19%) | catalogued as rs1390998854, COSV58951435; called by muse, mutect2, varscan2
- LRRCC1 | c.2351G>A p.R784H | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT deleterious (0.05); PolyPhen benign (0.143); catalogued as rs758066481, COSV64483249; called by muse, mutect2, varscan2
- LRRN3 | c.1243A>G p.M415V | Missense Mutation (SNP) | VAF 79/579 reads (14%) | SIFT tolerated (0.08); PolyPhen benign (0.068); catalogued as rs1192824677; called by muse, mutect2, varscan2
- LSM4 | c.26C>T p.T9M | Missense Mutation (SNP) | VAF 11/172 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs1354802386; called by muse, mutect2
- LUZP1 | c.1208G>A p.R403Q | Missense Mutation (SNP) | VAF 48/252 reads (19%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.93); catalogued as rs765769791, COSV56502994; called by muse, mutect2, varscan2
- LYAR | c.1004del p.K335Rfs*3 | Frame Shift Del (DEL) | VAF 15/80 reads (19%) | catalogued as COSV104413868; called by mutect2, pindel, varscan2
- LYPD4 | c.565A>G p.M189V | Missense Mutation (SNP) | VAF 58/346 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.184); catalogued as rs1473667796; called by muse, mutect2, varscan2
- LZTS3 | c.1420C>T p.R474C (on ENST00000329152; = p.R428C on NM_001282533.2) | Missense Mutation (SNP) | VAF 57/259 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs866003582; called by muse, mutect2, varscan2
- M1AP | c.933-1G>T p.X311_splice | Splice Site (SNP) | VAF 31/132 reads (23%) | catalogued as COSV51849106; called by muse, mutect2, varscan2
- MAN2B1 | c.659G>A p.R220H | Missense Mutation (SNP) | VAF 106/500 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1310537291; called by muse, mutect2, varscan2
- MAP1B | c.6638G>A p.R2213H | Missense Mutation (SNP) | VAF 47/343 reads (14%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.854); catalogued as rs754794035, COSV57100897; called by muse, mutect2, varscan2
- MAP3K12 | c.1031G>A p.R344H | Missense Mutation (SNP) | VAF 38/245 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as rs199708842, COSV57235875; called by muse, mutect2, varscan2
- MAP3K13 | c.157C>T p.R53* | Nonsense Mutation (SNP) | VAF 65/353 reads (18%) | catalogued as COSV53998953; called by muse, mutect2, varscan2
- MAP4K2 | c.559C>T p.R187C | Missense Mutation (SNP) | VAF 126/672 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.283); catalogued as rs544731329; called by muse, mutect2, varscan2
- MAP7D3 | c.922dup p.Q308Pfs*25 | Frame Shift Ins (INS) | VAF 72/236 reads (31%) | catalogued as rs746202015; called by mutect2, varscan2
- MAPK8IP3 | c.2743C>T p.R915W | Missense Mutation (SNP) | VAF 74/454 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.895); catalogued as rs746106588, COSV51717219; called by muse, mutect2, varscan2
- MARCHF7 | c.886del p.S296Hfs*9 | Frame Shift Del (DEL) | VAF 33/174 reads (19%) | catalogued as rs1383130845; called by mutect2, varscan2
- MAT2A | c.986C>A p.S329Y | Missense Mutation (SNP) | VAF 34/155 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV52087137; called by muse, mutect2, varscan2
- MCEE | c.419del p.K140Rfs*6 | Frame Shift Del (DEL) | VAF 51/256 reads (20%) | catalogued as rs776473131; called by mutect2, varscan2
- MDN1 | c.5924del p.L1975Wfs*7 | Frame Shift Del (DEL) | VAF 11/64 reads (17%) | catalogued as rs1315305195; called by mutect2, pindel, varscan2
- MED12L | c.1011del p.G338Afs*4 | Frame Shift Del (DEL) | VAF 50/272 reads (18%) | catalogued as COSV56379857; called by mutect2, pindel, varscan2
- MED28 | c.22A>G p.M8V | Missense Mutation (SNP) | VAF 9/82 reads (11%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.824); catalogued as rs757784959, COSV52846188; called by mutect2, varscan2
- MEF2D | c.805G>A p.D269N | Missense Mutation (SNP) | VAF 61/313 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.198); catalogued as rs1346753846, COSV61728060; called by muse, mutect2, varscan2
- MEGF8 | c.683G>A p.R228H | Missense Mutation (SNP) | VAF 59/266 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1446825911, COSV52101260; called by muse, mutect2, varscan2
- MIA2 | c.1089del p.D364Tfs*8 | Frame Shift Del (DEL) | VAF 24/78 reads (31%) | catalogued as rs538500709; called by mutect2, varscan2
- MICAL3 | c.4213dup p.R1405Pfs*120 | Frame Shift Ins (INS) | VAF 77/428 reads (18%) | catalogued as rs1569078371; called by mutect2, pindel, varscan2
- MIDEAS | c.939del p.N314Tfs*4 | Frame Shift Del (DEL) | VAF 10/63 reads (16%) | catalogued as rs762448666; called by mutect2, pindel, varscan2
- MIIP | c.323G>A p.R108Q | Missense Mutation (SNP) | VAF 35/259 reads (14%) | SIFT tolerated (0.75); PolyPhen benign (0.015); catalogued as rs775285846; called by muse, mutect2, varscan2
- MIIP | c.878C>T p.P293L | Missense Mutation (SNP) | VAF 61/314 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs755192697, COSV99337742; called by muse, mutect2, varscan2
- MINK1 | c.1699_1701del p.P567del | In Frame Del (DEL) | VAF 42/239 reads (18%) | catalogued as rs1222838895; called by pindel, varscan2
- MISP | c.1363G>A p.A455T | Missense Mutation (SNP) | VAF 58/279 reads (21%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as rs1358825226; called by muse, mutect2, varscan2
- MKS1 | c.814G>A p.A272T | Missense Mutation (SNP) | VAF 102/509 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as rs886044205, COSV100439580, COSV58304856; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MLXIP | c.2470G>A p.V824M | Missense Mutation (SNP) | VAF 27/165 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as rs778593659, COSV100039193; called by muse, mutect2, varscan2
- MMP21 | c.641G>A p.R214H | Missense Mutation (SNP) | VAF 35/157 reads (22%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.607); catalogued as rs749881801, COSV64288545; called by muse, mutect2, varscan2
- MOCOS | c.*6del | Frame Shift Del (DEL) | VAF 24/233 reads (10%) | catalogued as rs755830405; called by mutect2, varscan2
- MOGS | c.1588G>A p.D530N | Missense Mutation (SNP) | VAF 117/670 reads (17%) | SIFT tolerated (0.2); PolyPhen benign (0.01); catalogued as rs749160883, COSV51971550; called by muse, mutect2, varscan2
- MOK | c.313del p.I105Lfs*25 | Frame Shift Del (DEL) | VAF 16/69 reads (23%) | catalogued as rs753079987; called by mutect2, varscan2
- MORC2 | c.1813-3del | Splice Region (DEL) | VAF 26/135 reads (19%) | catalogued as rs777649506, COSV53202254; called by mutect2, varscan2
- MORC4 | c.1489A>G p.M497V | Missense Mutation (SNP) | VAF 17/77 reads (22%) | SIFT tolerated (0.8); PolyPhen benign (0); catalogued as rs1234579325; called by muse, mutect2, varscan2
- MPLKIP | c.26del p.P9Qfs*144 | Frame Shift Del (DEL) | VAF 40/224 reads (18%) | catalogued as rs746094400; called by mutect2, varscan2
- MPO | c.1061G>A p.R354H | Missense Mutation (SNP) | VAF 94/587 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1399823848, COSV99832857; called by muse, mutect2, varscan2
- MPP4 | c.727C>T p.Q243* | Nonsense Mutation (SNP) | VAF 43/223 reads (19%) | catalogued as COSV100207254; called by muse, mutect2, varscan2
- MPP5 | c.173G>A p.R58H | Missense Mutation (SNP) | VAF 29/162 reads (18%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.719); catalogued as rs143923342; called by muse, mutect2, varscan2
- MPPED1 | c.107G>A p.R36Q | Missense Mutation (SNP) | VAF 116/584 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.286); catalogued as rs1414691897; called by muse, mutect2, varscan2
- MRE11 | c.1532del p.N511Ifs*13 | Frame Shift Del (DEL) | VAF 35/236 reads (15%) | catalogued as rs757691558; called by mutect2, pindel, varscan2
- MROH2A | c.3011C>T p.P1004L | Missense Mutation (SNP) | VAF 61/445 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.433); catalogued as rs771687908, COSV67680816; called by muse, mutect2, varscan2
- MROH5 | c.2119del p.Q707Rfs*29 | Frame Shift Del (DEL) | VAF 40/266 reads (15%) | catalogued as rs1374297035; called by mutect2, varscan2
- MRPL9 | c.571C>T p.R191C | Missense Mutation (SNP) | VAF 24/151 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0.025); catalogued as rs758235751, COSV58619953; called by muse, mutect2, varscan2
- MRPS18C | c.150+16del | Splice Region (DEL) | VAF 10/60 reads (17%) | catalogued as rs199634680; called by mutect2, varscan2
- MRTFB | c.1477G>A p.A493T | Missense Mutation (SNP) | VAF 104/546 reads (19%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as rs528040132, COSV104402771; called by muse, mutect2, varscan2
- MST1R | c.3914G>A p.R1305H | Missense Mutation (SNP) | VAF 50/158 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs373976686; called by muse, mutect2, varscan2
- MTSS1 | c.1379G>A p.S460N | Missense Mutation (SNP) | VAF 126/639 reads (20%) | SIFT tolerated (0.41); PolyPhen benign (0.001); catalogued as rs756281738; called by muse, mutect2, varscan2
- MUC16 | c.18109G>A p.G6037R | Missense Mutation (SNP) | VAF 78/404 reads (19%) | SIFT tolerated, low confidence (0.44); PolyPhen benign (0); catalogued as rs771448044, COSV67460293; called by muse, mutect2, varscan2
- MVB12B | c.202G>A p.V68I | Missense Mutation (SNP) | VAF 14/134 reads (10%) | SIFT tolerated (0.22); PolyPhen benign (0.049); catalogued as rs766510440, COSV63259497; called by muse, mutect2, varscan2
- MVD | c.869G>A p.R290H | Missense Mutation (SNP) | VAF 40/241 reads (17%) | SIFT tolerated (0.05); PolyPhen benign (0.006); catalogued as rs748943997; called by muse, mutect2, varscan2
- MXRA8 | c.901del p.R301Gfs*107 | Frame Shift Del (DEL) | VAF 108/329 reads (33%) | catalogued as rs764857791; called by mutect2, pindel, varscan2
- MYCBP2 | c.10456C>T p.R3486W (on ENST00000357337; = p.R3524W on NM_015057.5) | Missense Mutation (SNP) | VAF 27/158 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV100631279; called by muse, mutect2, varscan2
- MYH1 | c.3419G>A p.R1140H | Missense Mutation (SNP) | VAF 102/543 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.665); catalogued as rs779598062, COSV56846716; called by muse, mutect2, varscan2
- MYH10 | c.4838C>T p.A1613V | Missense Mutation (SNP) | VAF 68/384 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.57); catalogued as rs746613898, COSV52610925; called by muse, mutect2, varscan2
- MYH11 | c.3035C>T p.T1012M | Missense Mutation (SNP) | VAF 22/144 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.24); catalogued as rs373881911; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MYH11 | c.2734C>T p.R912W | Missense Mutation (SNP) | VAF 152/822 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs918714049, COSV55568193, COSV55572470; called by muse, varscan2
- MYL9 | c.28A>C p.T10P | Missense Mutation (SNP) | VAF 16/85 reads (19%) | SIFT tolerated (0.08); PolyPhen benign (0.036); catalogued as rs1419719022; called by muse, mutect2, varscan2
- MYLIP | c.52G>A p.E18K | Missense Mutation (SNP) | VAF 38/199 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.017); catalogued as rs745612454; called by muse, mutect2, varscan2
- MYLK3 | c.434G>A p.R145H | Missense Mutation (SNP) | VAF 68/352 reads (19%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as rs748998633; called by muse, mutect2, varscan2
- MYO15A | c.1334G>A p.R445H | Missense Mutation (SNP) | VAF 122/529 reads (23%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.401); catalogued as rs777527625, COSV52753801; called by muse, mutect2, varscan2
- MYO15A | c.6280C>T p.R2094C | Missense Mutation (SNP) | VAF 82/459 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs749332616; called by muse, mutect2, varscan2
- MYO16 | c.2525del p.F842Sfs*17 | Frame Shift Del (DEL) | VAF 18/78 reads (23%) | catalogued as rs761471964; called by mutect2, varscan2
- MYO16 | c.3961G>A p.A1321T | Missense Mutation (SNP) | VAF 102/532 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.199); catalogued as rs1430548215; called by muse, mutect2, varscan2
- MYO6 | c.596G>A p.R199H | Missense Mutation (SNP) | VAF 33/270 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as rs140235734, COSV64120895; called by muse, mutect2, varscan2
- NAAA | c.631C>T p.R211W | Missense Mutation (SNP) | VAF 31/188 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.606); catalogued as rs199653966, COSV54432425; called by muse, varscan2
- NAT8 | c.370G>A p.A124T | Missense Mutation (SNP) | VAF 95/611 reads (16%) | SIFT tolerated (0.05); PolyPhen benign (0.422); catalogued as rs778156959, COSV55542320; called by muse, mutect2, varscan2
- NAV2 | c.4487T>C p.L1496P (on ENST00000396087 / NM_001244963.2; = p.L1473P on NM_145117.5) | Missense Mutation (SNP) | VAF 37/249 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.034); catalogued as rs776278108; called by muse, mutect2, varscan2
- NBEAL2 | c.6178C>T p.R2060C | Missense Mutation (SNP) | VAF 36/111 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.134); catalogued as rs547933637; ClinVar: likely benign; called by muse, mutect2, varscan2
- NCKAP1L | c.82C>T p.R28C | Missense Mutation (SNP) | VAF 28/177 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs745617849, COSV53203606, COSV99515275; called by muse, mutect2, varscan2
- NCOA6 | c.4050del p.A1351Pfs*46 | Frame Shift Del (DEL) | VAF 65/320 reads (20%) | catalogued as COSV62868094; called by mutect2, pindel, varscan2
- NDST1 | c.1501G>A p.G501S | Missense Mutation (SNP) | VAF 78/418 reads (19%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.849); catalogued as rs1286119272; called by muse, mutect2, varscan2
- NDUFA10 | c.866G>A p.R289H | Missense Mutation (SNP) | VAF 69/363 reads (19%) | SIFT tolerated (0.57); PolyPhen possibly damaging (0.759); catalogued as rs557444462, COSV53152596; called by muse, mutect2, varscan2
- NECAB3 | c.289+8G>T | Splice Region (SNP) | VAF 20/84 reads (24%) | catalogued as rs766303303; called by muse, varscan2
- NECTIN4 | c.610G>A p.V204I | Missense Mutation (SNP) | VAF 136/665 reads (20%) | SIFT tolerated (0.06); PolyPhen benign (0.011); catalogued as rs371860245; called by muse, mutect2, varscan2
- NEIL3 | c.1777G>A p.A593T | Missense Mutation (SNP) | VAF 28/141 reads (20%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.993); catalogued as rs771744474; called by muse, mutect2, varscan2
- NELL1 | c.2290A>G p.R764G | Missense Mutation (SNP) | VAF 95/594 reads (16%) | SIFT tolerated (0.17); PolyPhen benign (0.039); catalogued as COSV54278341; called by muse, mutect2, varscan2
- NFASC | c.167G>A p.R56H (on ENST00000339876 / NM_001378329.1; = p.R50H on NM_015090.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 27/204 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.903); catalogued as rs747820571, COSV58362684; called by muse, mutect2, varscan2
- NIBAN3 | c.325C>T p.R109W | Missense Mutation (SNP) | VAF 32/192 reads (17%) | SIFT tolerated (0.19); PolyPhen benign (0.011); catalogued as rs536652149, COSV56308194; called by muse, mutect2, varscan2
- NID1 | c.2984C>T p.T995M | Missense Mutation (SNP) | VAF 25/159 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs761573061, COSV51619834; called by muse, mutect2, varscan2
- NID2 | c.1378C>T p.R460* | Nonsense Mutation (SNP) | VAF 54/304 reads (18%) | catalogued as rs1439975900; called by muse, mutect2, varscan2
- NKX6-1 | c.733G>A p.G245R | Missense Mutation (SNP) | VAF 31/206 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.103); catalogued as COSV99880193; called by muse, mutect2, varscan2
- NLRP1 | c.731C>T p.A244V | Missense Mutation (SNP) | VAF 35/187 reads (19%) | SIFT tolerated, low confidence (0.46); PolyPhen benign (0); catalogued as rs199648641, COSV99334640; called by muse, mutect2, varscan2
- NOD2 | c.1276C>T p.R426C | Missense Mutation (SNP) | VAF 221/1147 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs545466982, COSV100318711; called by muse, mutect2, varscan2
- NOL4L | c.396dup p.Y133Lfs*18 | Frame Shift Ins (INS) | VAF 27/193 reads (14%) | catalogued as rs751187638; called by mutect2, varscan2
- NOS3 | c.1319del p.G440Afs*64 | Frame Shift Del (DEL) | VAF 50/314 reads (16%) | catalogued as rs749517498, COSV52496454; called by mutect2, pindel, varscan2
- NPAT | c.380C>T p.A127V | Missense Mutation (SNP) | VAF 47/274 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.848); catalogued as COSV99586321; called by muse, mutect2, varscan2
- NPL | c.178G>A p.V60I | Missense Mutation (SNP) | VAF 105/559 reads (19%) | SIFT tolerated (0.57); PolyPhen benign (0.023); catalogued as rs769551750, COSV51125467; called by muse, mutect2, varscan2
- NPY4R | c.377C>T p.T126M | Missense Mutation (SNP) | VAF 41/369 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); catalogued as rs149694580; called by muse, mutect2, varscan2
- NRCAM | c.2645G>A p.R882Q (on ENST00000379028 / NM_001371124.1; = p.R866Q on NM_005010.4 and 21 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 32/130 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.327); catalogued as rs746161292, COSV61038655; called by muse, mutect2, varscan2
- NRXN2 | c.1537C>T p.R513C | Missense Mutation (SNP) | VAF 95/461 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.062); catalogued as rs1448509951; called by muse, mutect2, varscan2
- NUMB | c.586C>T p.R196C (on ENST00000355058; = p.R185C on NM_003744.5) | Missense Mutation (SNP) | VAF 85/446 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs748636568, COSV61830387, COSV61832174; called by muse, mutect2, varscan2
- NUP98 | c.1846C>T p.R616C | Missense Mutation (SNP) | VAF 14/57 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.614); catalogued as rs758467022, COSV61439944; called by muse, mutect2, varscan2
- NUTM2E | c.1108C>T p.R370W | Missense Mutation (SNP) | VAF 97/743 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); catalogued as rs753824688; called by muse, mutect2, varscan2
- NYX | c.407G>A p.R136H | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT tolerated (0.18); PolyPhen benign (0.04); catalogued as COSV61180444; called by muse, mutect2, varscan2
- OBSCN | c.7664C>T p.A2555V | Missense Mutation (SNP) | VAF 80/415 reads (19%) | SIFT tolerated (0.11); PolyPhen benign (0.191); catalogued as rs769945926, COSV52780087; called by muse, mutect2, varscan2
- OBSL1 | c.4358G>A p.R1453Q | Missense Mutation (SNP) | VAF 28/131 reads (21%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.998); catalogued as rs1197623916, COSV54711127; called by muse, mutect2, varscan2
- OCIAD1 | c.328del p.G111Efs*28 | Frame Shift Del (DEL) | VAF 10/67 reads (15%) | catalogued as COSV51901916; called by mutect2, pindel, varscan2
- OGFR | c.1406C>T p.A469V | Missense Mutation (SNP) | VAF 39/568 reads (7%) | SIFT tolerated (0.14); PolyPhen benign (0.051); catalogued as rs756726195; called by muse, mutect2
- OGFR | c.1846G>A p.E616K | Missense Mutation (SNP) | VAF 86/520 reads (17%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0); catalogued as rs200564392; called by mutect2, varscan2
- ONECUT1 | c.1042C>T p.R348W | Missense Mutation (SNP) | VAF 117/476 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1297378279; called by muse, mutect2, varscan2
- OR10Z1 | c.542C>T p.T181M | Missense Mutation (SNP) | VAF 150/828 reads (18%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.49); catalogued as rs745847083; called by mutect2, varscan2
- OR13C8 | c.518T>C p.V173A | Missense Mutation (SNP) | VAF 116/682 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.17); catalogued as rs765815342; called by muse, mutect2, varscan2
- OR1D5 | c.365G>A p.R122H | Missense Mutation (SNP) | VAF 169/1011 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.141); catalogued as rs768209356; called by muse, mutect2, varscan2
- OR1J1 | c.758G>A p.R253Q | Missense Mutation (SNP) | VAF 54/561 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.013); catalogued as rs562608809; called by muse, mutect2, varscan2
- OR1J1 | c.461C>T p.A154V | Missense Mutation (SNP) | VAF 101/510 reads (20%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.125); catalogued as rs762965619, COSV52237360, COSV52239396; called by muse, mutect2, varscan2
- OR1L8 | c.439G>A p.A147T | Missense Mutation (SNP) | VAF 60/255 reads (24%) | SIFT tolerated (0.3); PolyPhen benign (0.006); catalogued as rs1266657181; called by muse, mutect2, varscan2
- OR2AJ1 | c.392G>A p.R131H | Missense Mutation (SNP) | VAF 83/562 reads (15%) | SIFT tolerated (0.73); PolyPhen benign (0.003); catalogued as rs754846040; called by muse, mutect2, varscan2
- OR4K17 | c.680A>G p.N227S | Missense Mutation (SNP) | VAF 93/528 reads (18%) | SIFT tolerated (0.24); PolyPhen benign (0.006); catalogued as rs771991458; called by muse, mutect2, varscan2
- OR4M1 | c.656C>T p.A219V | Missense Mutation (SNP) | VAF 74/1102 reads (7%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as rs374347736; called by muse, mutect2
- OR5D18 | c.704G>A p.R235H | Missense Mutation (SNP) | VAF 86/503 reads (17%) | SIFT tolerated (0.14); PolyPhen benign (0.029); catalogued as rs112309559; called by muse, mutect2, varscan2
- OR6C4 | c.749A>C p.Y250S | Missense Mutation (SNP) | VAF 19/235 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.97); catalogued as COSV67792802; called by muse, mutect2
- OR6P1 | c.96del p.F32Lfs*6 | Frame Shift Del (DEL) | VAF 22/128 reads (17%) | catalogued as rs201077183; called by mutect2, varscan2
- OR8B4 | c.469G>A p.A157T | Missense Mutation (SNP) | VAF 104/664 reads (16%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.117); catalogued as COSV100635885; called by muse, mutect2, varscan2
- OSBPL6 | c.2366C>T p.A789V | Missense Mutation (SNP) | VAF 15/99 reads (15%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99508874; called by muse, mutect2, varscan2
- OSGEPL1 | c.36del p.F12Lfs*12 | Frame Shift Del (DEL) | VAF 20/103 reads (19%) | catalogued as rs750679212; called by mutect2, varscan2
- OTOG | c.2371G>A p.A791T | Missense Mutation (SNP) | VAF 41/392 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.007); catalogued as rs1489143378, COSV61131963; called by muse, mutect2, varscan2
- OVOL1 | c.575A>G p.H192R | Missense Mutation (SNP) | VAF 83/531 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60120522; called by muse, mutect2, varscan2
- OVOL3 | c.73C>T p.R25W | Missense Mutation (SNP) | VAF 51/316 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.611); catalogued as rs761040426; called by muse, mutect2, varscan2
- P2RX2 | c.1061T>C p.V354A (on ENST00000343948 / NM_170683.4; = p.V282A on NM_012226.5) | Missense Mutation (SNP) | VAF 17/147 reads (12%) | SIFT tolerated (0.38); PolyPhen probably damaging (0.911); catalogued as COSV57677019; called by muse, mutect2, varscan2
- P2RY6 | c.113C>T p.A38V | Missense Mutation (SNP) | VAF 46/790 reads (6%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs772275313; called by muse, mutect2
- PAK5 | c.1957C>T p.R653W | Missense Mutation (SNP) | VAF 65/313 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs769363113; called by muse, mutect2, varscan2
- PANK4 | c.175G>A p.A59T | Missense Mutation (SNP) | VAF 71/426 reads (17%) | SIFT tolerated (0.15); PolyPhen benign (0.302); catalogued as rs903032523; called by muse, mutect2, varscan2
- PAOX | c.1286G>A p.S429N | Missense Mutation (SNP) | VAF 44/228 reads (19%) | SIFT tolerated (0.05); PolyPhen benign (0.263); catalogued as rs1259397439; called by muse, mutect2, varscan2
- PAPPA2 | c.3845del p.L1282* | Frame Shift Del (DEL) | VAF 20/138 reads (14%) | catalogued as rs1558553713; called by mutect2, pindel, varscan2
- PAQR4 | c.481G>A p.G161S | Missense Mutation (SNP) | VAF 65/341 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.233); catalogued as rs566373345, COSV99234321; called by muse, mutect2, varscan2
- PARD3B | c.2509del p.T837Rfs*13 (on ENST00000406610 / NM_001302769.2; = p.T768Rfs*13 on NM_057177.7) | Frame Shift Del (DEL) | VAF 60/312 reads (19%) | catalogued as rs772816756; called by mutect2, varscan2
- PARP4 | c.5065C>T p.R1689W | Missense Mutation (SNP) | VAF 14/136 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs756987701; called by muse, mutect2, varscan2
- PAXIP1 | c.300del p.F100Lfs*31 | Frame Shift Del (DEL) | VAF 9/44 reads (20%) | catalogued as rs753190856; called by mutect2, varscan2
- PCDHA12 | c.2339G>A p.R780Q | Missense Mutation (SNP) | VAF 21/115 reads (18%) | SIFT tolerated, low confidence (0.63); PolyPhen benign (0.001); catalogued as COSV56475281; called by muse, mutect2, varscan2
- PCDHA8 | c.1367C>T p.A456V | Missense Mutation (SNP) | VAF 269/1421 reads (19%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.074); catalogued as rs781956622, COSV100970348, COSV99061472; called by muse, mutect2, varscan2
- PCDHA8 | c.2294C>T p.P765L | Missense Mutation (SNP) | VAF 61/310 reads (20%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.003); catalogued as rs111750019, COSV65324727; called by muse, mutect2, varscan2
- PCDHB8 | c.1540C>A p.L514M | Missense Mutation (SNP) | VAF 312/1679 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV50754678, COSV50762938; called by muse, varscan2
- PCDHGA10 | c.2302C>T p.R768* | Nonsense Mutation (SNP) | VAF 36/623 reads (6%) | catalogued as COSV53964249; called by muse, mutect2
- PCIF1 | c.1045G>A p.V349I | Missense Mutation (SNP) | VAF 34/150 reads (23%) | SIFT tolerated (0.23); PolyPhen benign (0.019); catalogued as rs1043486085; called by muse, varscan2
- PCNX3 | c.3136C>T p.R1046C | Missense Mutation (SNP) | VAF 63/335 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.585); catalogued as rs1272552644, COSV63141260; called by muse, mutect2, varscan2
- PCNX3 | c.4564G>A p.G1522S | Missense Mutation (SNP) | VAF 138/701 reads (20%) | SIFT tolerated (0.21); PolyPhen benign (0.071); catalogued as rs767095476; called by muse, mutect2, varscan2
- PCSK9 | c.1540G>A p.A514T | Missense Mutation (SNP) | VAF 193/969 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.75); catalogued as rs1447116791, CM084650, COSV56162774; called by muse, mutect2, varscan2
- PDE2A | c.1538-3C>T | Splice Region (SNP) | VAF 56/307 reads (18%) | catalogued as rs1489666148; called by muse, mutect2, varscan2
- PDILT | c.859G>A p.E287K | Missense Mutation (SNP) | VAF 35/187 reads (19%) | SIFT tolerated (0.37); PolyPhen benign (0.015); catalogued as rs778919842, COSV56706493; called by muse, mutect2, varscan2
- PDK2 | c.358C>T p.R120W | Missense Mutation (SNP) | VAF 86/396 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs949061535, COSV50303288; called by muse, mutect2, varscan2
- PEG3 | c.1832G>A p.S611N | Missense Mutation (SNP) | VAF 45/260 reads (17%) | SIFT tolerated (0.39); PolyPhen benign (0.041); catalogued as COSV55634745, COSV99686673; called by muse, mutect2, varscan2
- PELI1 | c.303G>T p.Q101H | Missense Mutation (SNP) | VAF 10/52 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV62731003; called by muse, mutect2, varscan2
- PELI3 | c.1283G>A p.R428H | Missense Mutation (SNP) | VAF 77/442 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.806); catalogued as rs758623139; called by muse, mutect2, varscan2
- PEX14 | c.1096C>T p.R366W | Missense Mutation (SNP) | VAF 81/355 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as rs758008527; called by muse, mutect2, varscan2
- PFKFB3 | c.466G>A p.D156N | Missense Mutation (SNP) | VAF 36/230 reads (16%) | PolyPhen benign (0.045); catalogued as rs756527360; called by muse, mutect2, varscan2
- PFKL | c.1267C>T p.R423W | Missense Mutation (SNP) | VAF 30/141 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1205707513; called by muse, varscan2
- PGPEP1 | c.127C>T p.H43Y | Missense Mutation (SNP) | VAF 37/196 reads (19%) | SIFT tolerated (0.52); PolyPhen benign (0.011); catalogued as rs773630445; called by muse, mutect2, varscan2
- PHACTR4 | c.159_160del p.S54* (on ENST00000373839 / NM_001350159.2; = p.S64* on NM_023923.4) | Frame Shift Del (DEL) | VAF 18/55 reads (33%) | catalogued as rs761437290; called by mutect2, varscan2
- PHB2 | c.391C>T p.R131* | Nonsense Mutation (SNP) | VAF 119/577 reads (21%) | catalogued as rs782322400, COSV54642058; called by muse, mutect2, varscan2
- PHC1 | c.2576G>A p.R859H | Missense Mutation (SNP) | VAF 19/144 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as rs773681618, COSV50002982; called by muse, mutect2, varscan2
- PHETA1 | c.178G>A p.V60I | Missense Mutation (SNP) | VAF 80/353 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.876); catalogued as rs145706089, COSV104422060; called by muse, mutect2, varscan2
- PHF14 | c.997G>A p.A333T | Missense Mutation (SNP) | VAF 9/85 reads (11%) | SIFT tolerated (0.25); PolyPhen benign (0.169); catalogued as rs542396851; called by mutect2, varscan2
- PHF2 | c.1475del p.K492Rfs*6 | Frame Shift Del (DEL) | VAF 36/188 reads (19%) | catalogued as rs769717544; called by mutect2, varscan2
- PHF21B | c.187G>A p.G63R | Missense Mutation (SNP) | VAF 18/121 reads (15%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.999); catalogued as rs369146125; called by muse, mutect2, varscan2
- PHGR1 | c.109del p.H37Tfs*71 | Frame Shift Del (DEL) | VAF 28/131 reads (21%) | catalogued as rs1264440278; called by pindel, varscan2
- PHKA2 | c.671G>A p.R224H | Missense Mutation (SNP) | VAF 78/231 reads (34%) | SIFT tolerated (0.06); PolyPhen benign (0.009); catalogued as rs1202167585, COSV66052129; called by muse, mutect2, varscan2
- PIEZO2 | c.5590G>A p.D1864N | Missense Mutation (SNP) | VAF 71/389 reads (18%) | SIFT tolerated (0.16); PolyPhen benign (0.089); catalogued as rs1021263575, COSV99555236; called by muse, mutect2, varscan2
- PIGR | c.1711C>T p.R571C | Missense Mutation (SNP) | VAF 42/225 reads (19%) | SIFT deleterious (0.05); PolyPhen benign (0.27); catalogued as rs765512951; called by muse, mutect2, varscan2
- PKIG | c.103G>A p.V35M | Missense Mutation (SNP) | VAF 36/227 reads (16%) | SIFT tolerated (0.66); PolyPhen benign (0.24); catalogued as rs200673295; called by muse, mutect2, varscan2
- PLA2G2F | c.539A>G p.Y180C | Missense Mutation (SNP) | VAF 143/727 reads (20%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.871); catalogued as COSV64279955; called by muse, mutect2, varscan2
- PLCXD1 | c.230C>T p.T77M | Missense Mutation (SNP) | VAF 18/344 reads (5%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.841); catalogued as rs749603595, COSV67541792; called by muse, mutect2
- PLEC | c.12004C>T p.R4002C (on ENST00000322810 / NM_201380.4; = p.R3892C on NM_000445.5) | Missense Mutation (SNP) | VAF 28/360 reads (8%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.548); catalogued as rs782679722; called by muse, mutect2
- PLEKHA5 | c.2995del p.T999Lfs*17 | Frame Shift Del (DEL) | VAF 9/37 reads (24%) | catalogued as rs759995048, COSV54701412; called by mutect2, varscan2
- PLEKHA6 | c.1798C>T p.R600C | Missense Mutation (SNP) | VAF 28/273 reads (10%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.95); catalogued as rs779750332, COSV55329672, COSV55338403; called by muse, mutect2, varscan2
- PLEKHA7 | c.2405del p.F802Sfs*21 | Frame Shift Del (DEL) | VAF 36/164 reads (22%) | catalogued as rs1333390805, COSV63043367; called by mutect2, varscan2
- PLEKHA7 | c.1097C>T p.S366L | Missense Mutation (SNP) | VAF 90/840 reads (11%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as rs1356472467; called by muse, mutect2, varscan2
- PLEKHG1 | c.1214G>A p.R405H | Missense Mutation (SNP) | VAF 26/166 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.7); catalogued as rs765761463, COSV62047776, COSV62049213; called by muse, mutect2, varscan2
- PLEKHG6 | c.1843C>T p.R615W | Missense Mutation (SNP) | VAF 48/264 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.719); catalogued as rs746952481; called by muse, varscan2
- PLEKHH3 | c.1912C>T p.R638W | Missense Mutation (SNP) | VAF 19/67 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.739); catalogued as rs765270762; called by muse, mutect2, varscan2
- PLEKHH3 | c.1339G>A p.A447T | Missense Mutation (SNP) | VAF 23/127 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV52217235; called by muse, mutect2, varscan2
- PLK2 | c.173A>G p.H58R | Missense Mutation (SNP) | VAF 76/370 reads (21%) | SIFT tolerated (0.57); PolyPhen benign (0.006); catalogued as rs1220797866; called by muse, varscan2
- PLK2 | c.151G>A p.V51M | Missense Mutation (SNP) | VAF 65/401 reads (16%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.031); catalogued as rs770678414; called by muse, varscan2
- PLN | c.74G>A p.R25H | Missense Mutation (SNP) | VAF 96/526 reads (18%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.415); catalogued as rs1004405095; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PLXNA2 | c.2081G>A p.R694Q | Missense Mutation (SNP) | VAF 28/111 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); catalogued as rs369300149; called by muse, mutect2, varscan2
- PNPLA5 | c.318del p.D107Tfs*14 | Frame Shift Del (DEL) | VAF 37/248 reads (15%) | catalogued as rs747771692; called by mutect2, pindel, varscan2
- PNPLA6 | c.3985G>A p.G1329R (on ENST00000414982 / NM_001166111.2; = p.G1281R on NM_006702.5) | Missense Mutation (SNP) | VAF 139/674 reads (21%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.812); catalogued as rs140568070, COSV55380238; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PODN | c.1751C>T p.A584V (on ENST00000395871; = p.A536V on NM_153703.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 26/292 reads (9%) | SIFT tolerated (0.72); PolyPhen benign (0.003); catalogued as rs1415501705, COSV57014428; called by muse, mutect2
- POLD1 | c.343C>G p.P115A | Missense Mutation (SNP) | VAF 107/521 reads (21%) | SIFT tolerated (0.07); PolyPhen benign (0.097); catalogued as rs754917939, COSV101486926; called by muse, mutect2, varscan2
- POLD3 | c.898del p.R300Gfs*5 | Frame Shift Del (DEL) | VAF 20/66 reads (30%) | catalogued as rs761423306, COSV55240660; called by mutect2, varscan2
- POLE | c.4847A>G p.K1616R | Missense Mutation (SNP) | VAF 78/467 reads (17%) | SIFT tolerated (0.35); PolyPhen benign (0.007); catalogued as rs747323052; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- POLM | c.290del p.P97Qfs*6 | Frame Shift Del (DEL) | VAF 48/201 reads (24%) | catalogued as rs745933237; called by mutect2, pindel, varscan2
- POLR1B | c.2407G>A p.V803I | Missense Mutation (SNP) | VAF 59/276 reads (21%) | SIFT tolerated (0.41); PolyPhen benign (0.003); catalogued as rs779282177; called by muse, mutect2, varscan2
- POLR2M | c.712C>T p.R238* | Nonsense Mutation (SNP) | VAF 53/277 reads (19%) | catalogued as rs746134082; called by muse, mutect2, varscan2
- POM121L2 | c.2932C>A p.Q978K | Missense Mutation (SNP) | VAF 38/203 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs1485036815; called by muse, mutect2, varscan2
- POMC | c.707G>A p.R236H | Missense Mutation (SNP) | VAF 71/391 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1237859972, COSV99256689; called by muse, mutect2, varscan2
- POMT1 | c.1261del p.L421* | Frame Shift Del (DEL) | VAF 81/501 reads (16%) | catalogued as rs749018170; called by mutect2, pindel, varscan2
- POTEH | c.605A>G p.D202G | Missense Mutation (SNP) | VAF 71/1072 reads (7%) | SIFT tolerated (0.34); PolyPhen benign (0.137); catalogued as COSV100625097; called by muse, mutect2
- PPFIA3 | c.943G>A p.A315T | Missense Mutation (SNP) | VAF 12/174 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.015); catalogued as COSV100494689, COSV61953832; called by muse, mutect2
- PPFIA3 | c.2912G>A p.R971H | Missense Mutation (SNP) | VAF 49/186 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV99418305; called by muse, mutect2, varscan2
- PPIG | c.2042del p.K681Rfs*12 | Frame Shift Del (DEL) | VAF 11/65 reads (17%) | catalogued as rs775130624; called by mutect2, pindel, varscan2
- PPM1N | c.301G>A p.V101I | Missense Mutation (SNP) | VAF 24/117 reads (21%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.972); catalogued as rs749745401; called by muse, mutect2, varscan2
- PPP1R2B | c.533C>T p.A178V | Missense Mutation (SNP) | VAF 68/455 reads (15%) | SIFT tolerated (0.14); PolyPhen benign (0.082); catalogued as rs780493385; called by muse, mutect2, varscan2
- PPP2R3C | c.67del p.S23Vfs*5 | Frame Shift Del (DEL) | VAF 20/56 reads (36%) | catalogued as rs758484975; called by mutect2, varscan2
- PPP4R3A | c.1637C>T p.S546L (on ENST00000554943 / NM_001366432.1; = p.S533L on NM_001284280.1) | Missense Mutation (SNP) | VAF 13/65 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as COSV100466817, COSV61504151, COSV61505250; called by muse, mutect2, varscan2
- PRKX | c.985G>A p.D329N | Missense Mutation (SNP) | VAF 31/69 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs141993152, COSV53324343; called by muse, mutect2, varscan2
- PRR22 | c.751A>G p.S251G | Missense Mutation (SNP) | VAF 27/164 reads (16%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as rs778215850; called by muse, mutect2, varscan2
- PRTN3 | c.115C>T p.R39W | Missense Mutation (SNP) | VAF 45/177 reads (25%) | SIFT tolerated (0.11); PolyPhen benign (0.151); catalogued as rs1470337010; called by muse, mutect2, varscan2
- PSMA6 | c.334G>A p.D112N | Missense Mutation (SNP) | VAF 22/158 reads (14%) | SIFT tolerated (0.06); PolyPhen benign (0.168); catalogued as rs763405168; called by muse, mutect2, varscan2
- PSPH | c.193C>T p.R65C | Missense Mutation (SNP) | VAF 63/345 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1393023702; called by muse, mutect2, varscan2
- PTDSS1 | c.1046G>A p.R349H | Missense Mutation (SNP) | VAF 32/190 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61264202, COSV61265816; called by muse, mutect2, varscan2
- PTH2R | c.302G>A p.R101Q | Missense Mutation (SNP) | VAF 32/169 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs267599176, COSV55913684; called by muse, mutect2, varscan2
- PTPN14 | c.2455C>T p.R819W | Missense Mutation (SNP) | VAF 57/339 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1216793547, COSV65284103; called by muse, mutect2, varscan2
- PTPRF | c.3193G>A p.A1065T | Missense Mutation (SNP) | VAF 94/415 reads (23%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs749489783; called by muse, mutect2, varscan2
- PUSL1 | c.166C>T p.P56S | Missense Mutation (SNP) | VAF 10/62 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.946); catalogued as rs1320673830; called by muse, mutect2, varscan2
- PXDNL | c.2879G>A p.R960Q | Missense Mutation (SNP) | VAF 46/211 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs762305176, COSV100685055, COSV62479321; called by muse, mutect2, varscan2
- PYGB | c.911C>T p.T304M | Missense Mutation (SNP) | VAF 44/267 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.989); catalogued as rs997828104; called by muse, mutect2, varscan2
- PYGB | c.1888G>A p.V630I | Missense Mutation (SNP) | VAF 58/339 reads (17%) | SIFT tolerated (0.22); PolyPhen benign (0.003); catalogued as rs149134071; called by muse, mutect2, varscan2
- RAB3GAP2 | c.2459G>T p.W820L | Missense Mutation (SNP) | VAF 31/226 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62783802; called by muse, mutect2, varscan2
- RAD51AP1 | c.208del p.R70Dfs*21 (on ENST00000228843 / NM_001130862.2; = p.R70Gfs*4 on NM_006479.5) | Frame Shift Del (DEL) | VAF 15/59 reads (25%) | catalogued as rs745353960; called by mutect2, pindel, varscan2
- RADIL | c.979G>A p.V327I | Missense Mutation (SNP) | VAF 93/499 reads (19%) | SIFT tolerated (0.2); PolyPhen benign (0.031); catalogued as rs1203516800; called by muse, mutect2, varscan2
- RAPSN | c.724C>T p.R242W | Missense Mutation (SNP) | VAF 147/730 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1005550058, CM094597; called by muse, mutect2, varscan2
- RASSF5 | c.114del p.D39Tfs*127 | Frame Shift Del (DEL) | VAF 14/80 reads (18%) | catalogued as rs1344667401; called by mutect2, pindel, varscan2
- RBM25 | c.1250G>A p.R417Q | Missense Mutation (SNP) | VAF 9/54 reads (17%) | SIFT tolerated (0.43); PolyPhen possibly damaging (0.602); catalogued as rs1364276493, COSV56202337; called by muse, mutect2, varscan2
- RBM26 | c.2181del p.K727Nfs*5 (on ENST00000438737 / NM_001366735.2; = p.K700Nfs*5 on NM_022118.5) | Frame Shift Del (DEL) | VAF 14/76 reads (18%) | catalogued as rs751690893; called by mutect2, varscan2
- RBM26 | c.1408C>T p.P470S | Missense Mutation (SNP) | VAF 11/125 reads (9%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.996); catalogued as rs866978160; called by muse, mutect2
- RBM45 | c.1149del p.A384Lfs*7 (on ENST00000616198 / NM_001365579.1; = p.A382Lfs*7 on NM_152945.4 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 16/90 reads (18%) | catalogued as rs749563266; called by mutect2, varscan2
- RC3H1 | c.838C>T p.R280W | Missense Mutation (SNP) | VAF 24/182 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs765313753, COSV51211649; called by muse, mutect2, varscan2
1,915 further variants in this file (1,055 protein-altering or splice-affecting, 498 silent, 362 other) are not listed here.
